Somatic mutation profile of tumor specimen TCGA-EE-A2GJ-06A (aliquot TCGA-EE-A2GJ-06A-11D-A196-08) from TCGA case TCGA-EE-A2GJ, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-EE-A2GJ-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 55611d3d-a88a-4b86-ae1b-467599192f9a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A2GJ-10A (Blood Derived Normal), aliquot TCGA-EE-A2GJ-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1e2fbcd3-fa2d-436c-adc8-ba5ce29f534a

The open-access MAF lists 1,427 somatic variants for this specimen: 900 protein-altering or splice-affecting, 496 silent, 31 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 815, Silent 496, Nonsense Mutation 49, Splice Region 21, Intron 13, RNA 11, Splice Site 9, 3'UTR 4, Frame Shift Del 4, 5'Flank 2, Frame Shift Ins 1, 5'UTR 1.

Variants (750 of 1,427; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1517G>A p.G506E (on ENST00000288602 / NM_001374244.1; = p.G466E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs121913351, CM115083, COSV56057462, COSV56059390, COSV56070593; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DYSF | c.5607G>A p.W1869* | Nonsense Mutation (SNP) | VAF 64/102 reads (63%) | catalogued as rs1558787893, COSV50459923; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EPHA7 | c.1967G>A p.G656E | Missense Mutation (SNP) | VAF 44/184 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65180770; called by muse, varscan2
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 76/149 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PGR | c.2507G>A p.R836Q | Missense Mutation (SNP) | VAF 22/52 reads (42%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as rs1000609240, COSV54795429; called by muse, mutect2
- TP53 | c.582del p.I195Sfs*52 | Frame Shift Del (DEL) | VAF 13/30 reads (43%) | catalogued as rs1567552031, COSV52772013, COSV52864400, COSV53143214; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCA13 | c.9364G>A p.D3122N | Missense Mutation (SNP) | VAF 27/188 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs770825181, COSV71290648; called by muse, mutect2, varscan2
- ABCA13 | c.13846C>T p.P4616S | Missense Mutation (SNP) | VAF 46/70 reads (66%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1376055144, COSV68943888; called by muse, mutect2, varscan2
- ABCB1 | c.248G>A p.G83E | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.051); catalogued as COSV55955044; called by muse, mutect2, varscan2
- ABCC3 | c.1828G>A p.E610K | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV53324526; called by muse, mutect2, varscan2
- ABCG1 | c.276G>A p.W92* | Nonsense Mutation (SNP) | VAF 48/166 reads (29%) | catalogued as rs1272752933, COSV59206613; called by muse, mutect2, varscan2
- ABHD4 | c.337T>C p.F113L | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.914); catalogued as COSV53530015; called by muse, mutect2, varscan2
- AC005833.1 | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.497); catalogued as COSV52898826; called by muse, mutect2, varscan2
- AC011448.1 | c.154A>G p.K52E | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.338); catalogued as COSV99388887; called by muse, mutect2
- ACAA1 | c.1121C>T p.A374V | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57176427; called by muse, mutect2, varscan2
- ACAP3 | c.282C>T p.I94= | Splice Region (SNP) | VAF 36/111 reads (32%) | catalogued as COSV61222592; called by muse, mutect2, varscan2
- ACP6 | c.856T>G p.L286V | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.16); catalogued as COSV65076882, COSV65077306; called by muse, mutect2, varscan2
- ADAM7 | c.1240G>A p.E414K | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51542137; called by muse, mutect2, varscan2
- ADAMDEC1 | c.958G>A p.G320R | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56476003; called by muse, mutect2, varscan2
- ADAMTS14 | c.1924+1G>A p.X642_splice | Splice Site (SNP) | VAF 9/21 reads (43%) | catalogued as COSV64603647; called by muse, mutect2, varscan2
- ADAMTS20 | c.1318C>T p.P440S | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV67134180; called by muse, varscan2
- ADAMTS7 | c.3688C>T p.P1230S | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.335); catalogued as COSV66308087; called by muse, mutect2, varscan2
- ADAMTS9 | c.3262G>A p.D1088N | Missense Mutation (SNP) | VAF 156/506 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.444); catalogued as COSV55784404; called by muse, varscan2
- ADAMTSL3 | c.2350G>A p.V784I | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs750340028, COSV54455119; called by muse, varscan2
- ADAP2 | c.796G>A p.G266R | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV58296401; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.624G>A p.W208* | Nonsense Mutation (SNP) | VAF 114/209 reads (55%) | catalogued as COSV58442582, COSV58444697; called by muse, mutect2, varscan2
- ADGRV1 | c.7204G>A p.E2402K | Missense Mutation (SNP) | VAF 17/25 reads (68%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.72); catalogued as COSV67988749; called by muse, mutect2, varscan2
- ADH7 | c.572G>A p.G191E | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52921860; called by muse, varscan2
- ADH7 | c.422G>A p.R141K | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52920455; called by muse, varscan2
- ADRB1 | c.326T>G p.L109R | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV65168073; called by muse, mutect2, varscan2
- AGAP1 | c.716C>T p.S239F | Missense Mutation (SNP) | VAF 175/267 reads (66%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.986); catalogued as COSV58330926; called by muse, mutect2, varscan2
- AIM2 | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 51/320 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as rs376512880, COSV63700488; called by muse, mutect2, varscan2
- ALB | c.881C>T p.S294L | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.041); catalogued as rs774294755, COSV55738750, COSV55739357; called by muse, mutect2, varscan2
- ALPK2 | c.2069C>T p.S690F | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.69); PolyPhen benign (0.024); catalogued as rs200606212, COSV64493432; called by muse, mutect2, varscan2
- ALX3 | c.658G>A p.G220R | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.564); catalogued as COSV63928716; called by muse, mutect2, varscan2
- AMBRA1 | c.1123C>T p.Q375* (on ENST00000458649 / NM_001367468.1; = p.Q285* on NM_017749.3 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 57/177 reads (32%) | catalogued as COSV54057450; called by muse, mutect2, varscan2
- AMBRA1 | c.269C>T p.S90F | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1458404554, COSV54049169; called by muse, mutect2, varscan2
- AMPD1 | c.1525G>A p.G509R | Missense Mutation (SNP) | VAF 80/164 reads (49%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.997); catalogued as COSV62416907; called by muse, mutect2, varscan2
- AMPD3 | c.646C>T p.P216S (on ENST00000396553 / NM_001025389.2; = p.P225S on NM_000480.3) | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV67331484; called by muse, mutect2, varscan2
- AMPH | c.1608G>A p.Q536= | Splice Region (SNP) | VAF 17/133 reads (13%) | catalogued as COSV57747199; called by muse, mutect2, varscan2
- AMY1C | c.1039C>T p.P347S | Missense Mutation (SNP) | VAF 39/254 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs748751804, COSV64407770; called by muse, varscan2
- ANGPT1 | c.562C>T p.H188Y | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.212); catalogued as rs1402073355, COSV52445739; called by muse, mutect2, varscan2
- ANKIB1 | c.302C>T p.P101L | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); catalogued as COSV56058961; called by muse, mutect2, varscan2
- ANKRD34A | c.1013C>T p.P338L | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.72); PolyPhen benign (0.023); catalogued as COSV60161292; called by muse, mutect2
- ANO5 | c.254C>T p.S85F | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as COSV61087010; called by muse, mutect2, varscan2
- ANXA3 | c.221G>A p.G74D | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.861); catalogued as COSV53715481; called by muse, mutect2, varscan2
- AOX1 | c.655C>T p.P219S | Missense Mutation (SNP) | VAF 29/49 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as COSV65981191; called by muse, mutect2, varscan2
- APOB | c.13609G>A p.E4537K | Missense Mutation (SNP) | VAF 478/734 reads (65%) | SIFT tolerated (0.22); PolyPhen benign (0.019); catalogued as COSV51941393; called by muse, mutect2, varscan2
- APOB | c.9845G>A p.S3282N | Missense Mutation (SNP) | VAF 429/629 reads (68%) | SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as COSV51941401; called by muse, mutect2, varscan2
- APOB | c.8939C>T p.S2980F | Missense Mutation (SNP) | VAF 408/611 reads (67%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51941418; called by muse, mutect2, varscan2
- APOB | c.1960A>T p.K654* | Nonsense Mutation (SNP) | VAF 386/570 reads (68%) | catalogued as COSV51941430; called by muse, mutect2, varscan2
- AQP9 | c.291G>A p.M97I | Missense Mutation (SNP) | VAF 81/273 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.065); catalogued as COSV54969360, COSV54971869; called by muse, mutect2, varscan2
- ARAP2 | c.4823G>A p.R1608K | Missense Mutation (SNP) | VAF 42/136 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs751877814, COSV58288584; called by muse, mutect2, varscan2
- AREG | c.401G>A p.G134E | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.88); catalogued as COSV99144397; called by muse, mutect2, varscan2
- ARHGAP1 | c.523A>G p.K175E | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as COSV61735320; called by muse, mutect2, varscan2
- ARHGAP5 | c.3889C>T p.R1297C (on ENST00000345122 / NM_001030055.2; = p.R1296C on NM_001173.3) | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100565611, COSV61534876; called by muse, mutect2
- ARHGEF4 | c.1233G>A p.M411I | Missense Mutation (SNP) | VAF 40/63 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV58124789; called by muse, mutect2, varscan2
- ARID2 | c.2173C>T p.Q725* | Nonsense Mutation (SNP) | VAF 36/115 reads (31%) | catalogued as COSV57603793, COSV57616521; called by muse, mutect2, varscan2
- ARID3A | c.998G>A p.S333N | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55044974; called by muse, mutect2, varscan2
- ARID3B | c.1564G>A p.G522R (on ENST00000622429 / NM_001307939.1; = p.G521R on NM_006465.4) | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs1436641379, COSV60558157; called by muse, mutect2, varscan2
- ARL2 | c.92C>T p.T31I | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55861484; called by muse, mutect2, varscan2
- ARMC4 | c.2115A>C p.E705D | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.135); catalogued as COSV59466629; called by muse, mutect2, varscan2
- ARMH3 | c.334C>T p.H112Y | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1218069251, COSV60751128; called by muse, mutect2, varscan2
- ARNT | c.1040G>A p.S347N | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.094); catalogued as COSV100591398, COSV62231218; called by muse, mutect2, varscan2
- ARSJ | c.1343C>T p.A448V | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59538487; called by muse, mutect2, varscan2
- ASB2 | c.857A>G p.N286S | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.45); PolyPhen benign (0.289); catalogued as COSV60112753; called by muse, mutect2, varscan2
- ASTN2 | c.3733G>A p.E1245K (on ENST00000313400 / NM_001365069.1; = p.E1194K on NM_014010.5) | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.395); catalogued as COSV56000282; called by muse, varscan2
- ASXL3 | c.2990C>T p.P997L | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.023); catalogued as COSV52470754; called by muse, mutect2, varscan2
- ATG12 | c.257A>G p.D86G | Missense Mutation (SNP) | VAF 38/60 reads (63%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.534); catalogued as rs916554136, COSV57243349; called by muse, mutect2, varscan2
- ATP2A3 | c.1222G>A p.D408N | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV99988731; called by muse, mutect2, varscan2
- ATP2C2 | c.1981-2A>C p.X661_splice | Splice Site (SNP) | VAF 11/49 reads (22%) | catalogued as COSV52297792; called by muse, mutect2, varscan2
- ATP8B4 | c.1900G>A p.E634K | Missense Mutation (SNP) | VAF 38/135 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs866255846, COSV52712173; called by muse, mutect2, varscan2
- ATRNL1 | c.4111C>T p.L1371F | Missense Mutation (SNP) | VAF 43/76 reads (57%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.543); catalogued as rs781912076, COSV58095719; called by muse, mutect2, varscan2
- B3GALNT2 | c.949T>G p.Y317D | Missense Mutation (SNP) | VAF 45/101 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.175); catalogued as COSV64004195; called by muse, mutect2, varscan2
- BAAT | c.934C>T p.P312S | Missense Mutation (SNP) | VAF 43/85 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV52288195; called by muse, varscan2
- BARX2 | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55651171; called by muse, mutect2, varscan2
- BCL11A | c.1408G>A p.E470K (on ENST00000335712 / NM_001365609.1; = p.E504K on NM_018014.4) | Missense Mutation (SNP) | VAF 96/146 reads (66%) | SIFT tolerated (0.28); PolyPhen benign (0.084); catalogued as rs1272776396, COSV59633024; called by muse, mutect2, varscan2
- BCL6B | c.970G>A p.E324K | Missense Mutation (SNP) | VAF 50/102 reads (49%) | SIFT tolerated (0.45); PolyPhen benign (0.107); catalogued as rs768779742, COSV53427843; called by muse, mutect2, varscan2
- BIN2 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV57206209; called by mutect2, varscan2
- BMP3 | c.359C>T p.S120L | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs566868500, COSV51084589; called by muse, mutect2, varscan2
- BNIPL | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 50/139 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.393); catalogued as rs587607488, COSV54845615; called by muse, mutect2, varscan2
- BOD1L1 | c.5599G>A p.G1867R | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV50021770; called by muse, mutect2, varscan2
- BPIFC | c.110G>A p.R37K | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.98); PolyPhen benign (0.017); catalogued as COSV55913382; called by muse, mutect2, varscan2
- BPTF | c.8407C>T p.P2803S | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as COSV58840254; called by muse, mutect2, varscan2
- BRINP3 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 60/133 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV66529469; called by muse, mutect2, varscan2
- BRPF1 | c.493C>T p.H165Y | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.588); catalogued as COSV57406021; called by muse, mutect2, varscan2
- BTBD1 | c.941G>A p.R314Q | Missense Mutation (SNP) | VAF 71/202 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV55603550; called by muse, mutect2, varscan2
- BTN1A1 | c.1225C>T p.L409F | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.652); catalogued as COSV55068282; called by muse, mutect2, varscan2
- C12orf40 | c.1843G>A p.D615N | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV61130243; called by muse, mutect2, varscan2
- C12orf71 | c.219A>C p.Q73H | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.599); catalogued as COSV101460505, COSV70282771; called by muse, mutect2, varscan2
- C1RL | c.796G>A p.G266S | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs370976814, COSV56925736; called by muse, mutect2, varscan2
- C1orf43 | c.632C>T p.S211F (on ENST00000368521 / NM_001297718.2; = p.S177F on NM_015449.4) | Missense Mutation (SNP) | VAF 37/265 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.962); catalogued as COSV62966503; called by muse, mutect2, varscan2
- C2orf16 | c.1869A>C p.E623D | Missense Mutation (SNP) | VAF 36/57 reads (63%) | SIFT tolerated (0.44); PolyPhen benign (0.092); catalogued as COSV62676690; called by muse, mutect2, varscan2
- C4BPB | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV54691886; called by muse, mutect2, varscan2
- C8B | c.1718C>T p.P573L | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV64777515; called by muse, mutect2, varscan2
- C8orf33 | c.389C>T p.P130L | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); catalogued as COSV58895804; called by muse, mutect2, varscan2
- CA10 | c.476T>G p.I159S | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53356953; called by muse, mutect2, varscan2
- CA11 | c.881T>G p.L294W | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50033416; called by muse, mutect2, varscan2
- CACNA1B | c.738G>A p.M246I | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.17); PolyPhen benign (0.018); catalogued as COSV53133524; called by muse, mutect2, varscan2
- CACNA1C | c.2314G>A p.E772K | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.952); catalogued as rs1361366772, COSV59737769; called by muse, mutect2, varscan2
- CACNA1H | c.6499G>A p.E2167K | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.168); catalogued as COSV52355816; called by muse, mutect2, varscan2
- CACYBP | c.451C>T p.L151F | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.754); catalogued as rs1191531078, COSV62881311; called by muse, mutect2, varscan2
- CALCR | c.503G>A p.G168E | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as COSV64009420; called by muse, mutect2, varscan2
- CALML5 | c.364A>C p.M122L | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.208); catalogued as COSV66702617, COSV66702797; called by muse, mutect2, varscan2
- CAPN12 | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.317); catalogued as COSV61016915; called by muse, mutect2, varscan2
- CARD11 | c.3286G>A p.E1096K | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV67798459; called by muse, mutect2, varscan2
- CARD11 | c.1887T>G p.D629E | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.628); catalogued as COSV62755840; called by muse, mutect2, varscan2
- CAT | c.452C>T p.P151L | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV53811765, COSV99573353; called by muse, mutect2, varscan2
- CC2D2A | c.2648A>G p.Y883C | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.773); catalogued as COSV67504313; called by muse, mutect2, varscan2
- CCDC141 | c.3281T>G p.V1094G | Missense Mutation (SNP) | VAF 41/76 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); catalogued as COSV55376488; called by muse, mutect2, varscan2
- CCDC24 | c.461A>C p.N154T | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as COSV100530558, COSV100530990; called by muse, mutect2, varscan2
- CCDC60 | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); catalogued as rs764208425, COSV59540294; called by muse, mutect2, varscan2
- CCDC60 | c.1040G>A p.S347N | Missense Mutation (SNP) | VAF 44/142 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.724); catalogued as COSV100554564; called by muse, mutect2, varscan2
- CCDC60 | c.1040+1G>A p.X347_splice | Splice Site (SNP) | VAF 41/136 reads (30%) | catalogued as COSV100554565; called by muse, mutect2, varscan2
- CCDC68 | c.623G>A p.R208K | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61604050; called by muse, mutect2, varscan2
- CCDC68 | c.359G>A p.R120K | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV61604054; called by muse, mutect2, varscan2
- CCDC81 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 55/171 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.898); catalogued as COSV53579527; called by muse, mutect2, varscan2
- CCK | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs370480453; called by muse, mutect2, varscan2
- CCNB3 | c.941C>T p.S314F | Missense Mutation (SNP) | VAF 58/86 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV52075568; called by muse, mutect2
- CD163 | c.1244G>A p.G415E | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.576); catalogued as COSV63134388; called by muse, mutect2, varscan2
- CD163L1 | c.4112T>G p.L1371R | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV58018953; called by muse, mutect2, varscan2
- CD40 | c.715C>T p.P239S | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.72); PolyPhen benign (0.017); catalogued as COSV64847624; called by muse, mutect2, varscan2
- CD84 | c.509C>T p.P170L | Missense Mutation (SNP) | VAF 30/181 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100245780; called by muse, mutect2, varscan2
- CD84 | c.508C>T p.P170S | Missense Mutation (SNP) | VAF 30/182 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.617); catalogued as COSV100245783, COSV60868602; called by muse, mutect2, varscan2
- CDH15 | c.2347C>T p.P783S | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.038); catalogued as rs1185283384, COSV57027931; called by muse, mutect2, varscan2
- CDH23 | c.3778G>A p.E1260K | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.655); catalogued as rs752118060, COSV56456230, COSV56456628; called by muse, mutect2, varscan2
- CDH9 | c.2246C>T p.S749L | Missense Mutation (SNP) | VAF 54/91 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs1161575895, COSV50265477; called by muse, mutect2, varscan2
- CDHR5 | c.1312G>A p.V438M | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV57642650; called by muse, mutect2, varscan2
- CDK13 | c.2299A>T p.M767L | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.125); catalogued as COSV51702521; called by muse, mutect2, varscan2
- CEACAM20 | c.215T>G p.I72S | Missense Mutation (SNP) | VAF 113/408 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57601389, COSV57602180; called by muse, mutect2, varscan2
- CEACAM6 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 87/241 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as COSV52267617; called by muse, mutect2, varscan2
- CELSR1 | c.2375C>T p.S792F | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV53093425; called by muse, mutect2, varscan2
- CEP70 | c.637T>C p.L213= | Splice Region (SNP) | VAF 102/219 reads (47%) | catalogued as rs749866976, COSV53876441; called by muse, mutect2, varscan2
- CFAP52 | c.940A>C p.I314L | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV55346264; called by muse, mutect2, varscan2
- CFAP52 | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV55346282; called by muse, mutect2, varscan2
- CFAP54 | c.5176C>T p.L1726F | Missense Mutation (SNP) | VAF 38/152 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.139); catalogued as COSV61570579, COSV61572992; called by muse, mutect2, varscan2
- CFHR5 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 53/136 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV56820648; called by muse, mutect2, varscan2
- CFHR5 | c.401G>A p.W134* | Nonsense Mutation (SNP) | VAF 9/114 reads (8%) | catalogued as COSV56823636; called by muse, mutect2
- CHD5 | c.5593G>A p.E1865K | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99312319; called by muse, mutect2
- CHP2 | c.394T>G p.S132A | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.881); catalogued as COSV55650207; called by muse, mutect2, varscan2
- CHP2 | c.493G>A p.D165N | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV55650221; called by muse, mutect2, varscan2
- CIT | c.238+2T>G p.X80_splice | Splice Site (SNP) | VAF 42/138 reads (30%) | catalogued as COSV55873576; called by muse, mutect2, varscan2
- CKMT2 | c.397G>A p.G133S | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs564635201, COSV54173915; called by muse, mutect2, varscan2
- CLCN1 | c.2944G>A p.D982N | Missense Mutation (SNP) | VAF 55/131 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV58371324; called by muse, mutect2, varscan2
- CLEC18B | c.22C>T p.P8S | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.404); catalogued as COSV60578029; called by muse, mutect2, varscan2
- CLTC | c.2624C>T p.T875I | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV52249238; called by muse, mutect2, varscan2
- CLU | c.76G>A p.V26I | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT tolerated (0.53); PolyPhen benign (0.012); catalogued as rs1170008221, COSV57067228; called by muse, mutect2, varscan2
- CLVS1 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0.024); catalogued as rs1316816191, COSV57977827, COSV57979643; called by muse, mutect2, varscan2
- CLVS2 | c.724C>T p.P242S | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.559); catalogued as COSV51559258, COSV51560504, COSV99252977; called by muse, mutect2, varscan2
- CMTM1 | c.339G>A p.G113= (on ENST00000457188 / NM_181269.3; = p.G230= on NM_052999.4) | Splice Region (SNP) | VAF 12/36 reads (33%) | catalogued as rs141489184; called by muse, mutect2
- CNGA1 | c.182C>T p.S61F | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.364); catalogued as COSV62054341; called by muse, mutect2
- CNGB3 | c.1433G>A p.R478Q | Missense Mutation (SNP) | VAF 59/198 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs772270787, COSV60692245; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNGB3 | c.233C>T p.S78F | Missense Mutation (SNP) | VAF 99/324 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.233); catalogued as COSV60685142; called by muse, mutect2, varscan2
- CNKSR1 | c.1826G>A p.R609Q (on ENST00000374253 / NM_001297647.2; = p.R602Q on NM_006314.3) | Missense Mutation (SNP) | VAF 46/130 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs780446264, COSV58793698; called by muse, varscan2
- CNTN3 | c.1364G>A p.R455K | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV55176028; called by muse, mutect2, varscan2
- CNTN6 | c.658G>A p.G220S | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100610005; called by muse, mutect2, varscan2
- CNTNAP2 | c.961T>A p.F321I | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV62208497, COSV62211017; called by muse, mutect2, varscan2
- COL10A1 | c.1525C>T p.P509S | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as rs750042042, COSV54573523, COSV99684480; called by muse, mutect2, varscan2
- COL11A1 | c.1737G>A p.R579= | Splice Region (SNP) | VAF 30/111 reads (27%) | catalogued as COSV100615147, COSV62187936; called by muse, mutect2, varscan2
- COL14A1 | c.2515G>A p.E839K | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as rs1369694792, COSV52859133; called by muse, mutect2, varscan2
- COL17A1 | c.1558G>A p.E520K | Missense Mutation (SNP) | VAF 51/106 reads (48%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV62227734; called by muse, mutect2, varscan2
- COL19A1 | c.1201C>T p.P401S | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs745453987, COSV59572612, COSV59577478; called by muse, mutect2, varscan2
- COL19A1 | c.3302C>T p.A1101V | Missense Mutation (SNP) | VAF 59/211 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as rs753501507, COSV59577484; called by muse, mutect2, varscan2
- COL21A1 | c.2791G>A p.G931S | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55168957; called by muse, mutect2, varscan2
- COL23A1 | c.556C>T p.P186S | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.221); catalogued as COSV66791728, COSV66792842; called by muse, mutect2, varscan2
- COL2A1 | c.2411G>A p.G804E | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1286544132, CM940303, COSV61534890; called by muse, mutect2, varscan2
- COL2A1 | c.2410G>A p.G804R | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100475320, COSV61535514; called by muse, mutect2, varscan2
- COL4A1 | c.1391G>A p.G464E | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65427798; called by muse, mutect2, varscan2
- COL4A4 | c.27G>A p.M9I | Missense Mutation (SNP) | VAF 221/325 reads (68%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV61633674; called by muse, mutect2, varscan2
- COL6A3 | c.7610G>A p.G2537E | Missense Mutation (SNP) | VAF 140/190 reads (74%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV55095606; called by muse, mutect2, varscan2
- COL7A1 | c.2570C>T p.S857F | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV60397475; called by muse, mutect2, varscan2
- COL8A1 | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.212); catalogued as rs759314386, COSV53737008; called by muse, mutect2, varscan2
- CORIN | c.2099C>T p.S700F | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.168); catalogued as COSV56694029; called by muse, mutect2, varscan2
- CPD | c.3457A>T p.M1153L | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV56714008; called by muse, mutect2, varscan2
- CPSF1 | c.3239C>T p.S1080F | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1222181111, COSV58234234; called by muse, mutect2, varscan2
- CR1 | c.4886A>C p.H1629P | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV65459631; called by muse, mutect2
- CRACR2A | c.94C>T p.P32S | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV52910923; called by muse, mutect2, varscan2
- CRB1 | c.4206G>A p.M1402I | Missense Mutation (SNP) | VAF 51/144 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV66337047; called by muse, mutect2, varscan2
- CREB3L2 | c.837T>A p.Y279* | Nonsense Mutation (SNP) | VAF 54/185 reads (29%) | catalogued as COSV57796800; called by muse, mutect2, varscan2
- CREBRF | c.163C>T p.P55S | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.021); catalogued as COSV51634209; called by muse, mutect2, varscan2
- CRIM1 | c.2275G>A p.D759N | Missense Mutation (SNP) | VAF 76/117 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV54867084; called by muse, mutect2, varscan2
- CRISPLD2 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs765424522, COSV52280664; called by muse, mutect2, varscan2
- CRP | c.524G>A p.G175E | Missense Mutation (SNP) | VAF 75/362 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.672); catalogued as COSV99660411; called by muse, mutect2, varscan2
- CRP | c.523G>A p.G175R | Missense Mutation (SNP) | VAF 76/368 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.758); catalogued as COSV54813608, COSV99660414; called by muse, mutect2, varscan2
- CSMD1 | c.445G>A p.G149R | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68222578; called by muse, mutect2, varscan2
- CSMD3 | c.3151G>A p.E1051K (on ENST00000297405 / NM_001363185.1; = p.E947K on NM_052900.3) | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.603); catalogued as rs764801003, COSV52140582; called by muse, mutect2, varscan2
- CSMD3 | c.493G>A p.G165R | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV52225581; called by muse, mutect2, varscan2
- CUZD1 | c.986G>A p.R329K | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59027145; called by muse, mutect2, varscan2
- CWF19L2 | c.1925C>T p.S642F | Missense Mutation (SNP) | VAF 38/75 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV56515101; called by muse, mutect2, varscan2
- CX3CL1 | c.509C>T p.P170L | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV99136241; called by muse, mutect2, varscan2
- CYP11A1 | c.1456G>A p.E486K | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); catalogued as COSV51432897; called by muse, mutect2, varscan2
- CYP2A13 | c.1142G>A p.R381Q | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.463); catalogued as rs759711890, COSV100386613; called by muse, mutect2
- CYP2C19 | c.236G>A p.G79E | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64907269; called by muse, mutect2, varscan2
- CYP4A22 | c.347C>T p.S116F | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.492); catalogued as COSV53740994; called by muse, mutect2, varscan2
- CYP4Z1 | c.34C>T p.H12Y | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.103); catalogued as COSV61965428; called by muse, mutect2, varscan2
- CYP4Z1 | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as rs1206792114, COSV61964908; called by muse, mutect2, varscan2
- DAB1 | c.1558C>T p.P520S (on ENST00000371231; = p.P487S on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/143 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV64694264, COSV64696184; called by muse, mutect2, varscan2
- DAB1 | c.586C>T p.P196S | Missense Mutation (SNP) | VAF 45/149 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.493); catalogued as COSV59730786; called by muse, mutect2, varscan2
- DCAF11 | c.784G>A p.D262N | Missense Mutation (SNP) | VAF 52/192 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.034); catalogued as COSV58109659; called by muse, mutect2, varscan2
- DCAF5 | c.1892C>T p.S631L | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs770821356, COSV58460269; called by muse, mutect2, varscan2
- DCBLD1 | c.718G>A p.D240N | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.795); catalogued as rs1259568784, COSV51643001; called by muse, mutect2, varscan2
- DCC | c.668G>A p.G223E | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV59106013; called by muse, mutect2, varscan2
- DCLRE1C | c.1643G>C p.S548T (on ENST00000378278 / NM_001350965.2; = p.S433T on NM_022487.4) | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.994); catalogued as COSV100542982, COSV57954475; called by muse, mutect2, varscan2
- DCUN1D3 | c.653C>T p.P218L | Missense Mutation (SNP) | VAF 59/181 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100176703; called by muse, mutect2, varscan2
- DCUN1D3 | c.652C>T p.P218S | Missense Mutation (SNP) | VAF 60/181 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100176705; called by muse, mutect2, varscan2
- DDX58 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.211); catalogued as COSV65883712; called by muse, mutect2, varscan2
- DDX60 | c.2858G>A p.R953K | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as COSV67097524; called by muse, mutect2, varscan2
- DDX60 | c.454G>A p.D152N | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs545288798, COSV67097530; called by muse, mutect2, varscan2
- DDX60L | c.2636G>A p.G879E | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.519); catalogued as rs1481599134, COSV52716245; called by muse, mutect2, varscan2
- DENND3 | c.3258G>A p.E1086= | Splice Region (SNP) | VAF 15/57 reads (26%) | catalogued as COSV52803777; called by muse, mutect2, varscan2
- DENND5B | c.2639C>T p.S880F | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1031348286, COSV60904312, COSV99080244; called by muse, mutect2, varscan2
- DGKB | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.827); catalogued as COSV51779744; called by muse, mutect2, varscan2
- DHX8 | c.1136C>T p.P379L | Missense Mutation (SNP) | VAF 46/150 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV52254298; called by muse, mutect2, varscan2
- DIAPH3 | c.2438T>G p.V813G (on ENST00000400324 / NM_001042517.2; = p.V550G on NM_030932.3) | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1384521792, COSV57373167; called by muse, mutect2, varscan2
- DISP3 | c.527C>T p.P176L | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs1395667741, COSV53823673; called by muse, mutect2, varscan2
- DLG2 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0.025); catalogued as rs374177340, COSV101074026; called by muse, mutect2, varscan2
- DLGAP2 | c.1883C>T p.S628L | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs949370630, COSV70100249; called by muse, mutect2, varscan2
- DLGAP3 | c.857C>T p.P286L | Missense Mutation (SNP) | VAF 47/104 reads (45%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.541); catalogued as COSV52395202; called by muse, mutect2, varscan2
- DLGAP4 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.74); PolyPhen benign (0.269); catalogued as rs369666332; called by muse, mutect2, varscan2
- DMGDH | c.1126C>T p.P376S | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1455517170, COSV54860743; called by muse, mutect2, varscan2
- DMXL2 | c.4190G>A p.R1397Q | Missense Mutation (SNP) | VAF 72/276 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV51843783; called by muse, mutect2, varscan2
- DNAH10 | c.6965G>A p.W2322* (on ENST00000409039; = p.W2261* on NM_207437.3) | Nonsense Mutation (SNP) | VAF 18/48 reads (38%) | catalogued as COSV68996202; called by muse, mutect2, varscan2
- DNAH17 | c.7267C>T p.P2423S | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV67754143; called by muse, mutect2, varscan2
- DNAH8 | c.3254G>A p.R1085Q | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.58); PolyPhen benign (0.017); catalogued as rs267601013, COSV59454038; called by muse, mutect2, varscan2
- DNAH8 | c.11651C>T p.S3884F | Missense Mutation (SNP) | VAF 120/261 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59454539, COSV59459009; called by muse, varscan2
- DNAH8 | c.11703G>A p.W3901* | Nonsense Mutation (SNP) | VAF 138/330 reads (42%) | catalogued as COSV100543091; called by muse, varscan2
- DNAH8 | c.11704G>A p.E3902K | Missense Mutation (SNP) | VAF 139/332 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.05); catalogued as COSV100543094; called by muse, varscan2
- DOCK8 | c.5639G>A p.R1880K | Missense Mutation (SNP) | VAF 52/162 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.831); catalogued as COSV66620841, COSV66621304; called by muse, mutect2, varscan2
- DOCK8 | c.6133G>A p.E2045K | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66621307; called by muse, mutect2, varscan2
- DPT | c.45G>A p.M15I | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV63189586; called by muse, mutect2
- DPYD | c.989C>T p.S330L | Missense Mutation (SNP) | VAF 36/119 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.029); catalogued as rs777560627, COSV64603563; called by muse, mutect2, varscan2
- DPYD | c.611C>T p.S204F | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64594585; called by muse, mutect2, varscan2
- DSC1 | c.2380G>A p.G794R | Missense Mutation (SNP) | VAF 73/199 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.096); catalogued as COSV57145552; called by muse, mutect2, varscan2
- DSC1 | c.1418C>T p.P473L | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV57147631; called by muse, mutect2
- DSC2 | c.1249C>T p.L417F | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV104377993, COSV51866405; called by muse, mutect2, varscan2
- DSC2 | c.577G>A p.G193R | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51866420; called by muse, mutect2, varscan2
- DSC3 | c.2053G>A p.G685R | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as rs138482790; called by muse, mutect2, varscan2
- DSG1 | c.1958G>A p.G653E | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as COSV57133292; called by muse, mutect2
- DSG3 | c.2449G>A p.D817N | Missense Mutation (SNP) | VAF 44/93 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57127489; called by muse, mutect2, varscan2
- DSN1 | c.172A>G p.S58G | Missense Mutation (SNP) | VAF 68/202 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as COSV65519550; called by muse, mutect2, varscan2
- DTNBP1 | c.560C>T p.T187I | Missense Mutation (SNP) | VAF 82/385 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.549); catalogued as COSV59037390; called by muse, mutect2, varscan2
- DYNC2H1 | c.4960G>T p.E1654* | Nonsense Mutation (SNP) | VAF 16/39 reads (41%) | catalogued as COSV62098210; called by muse, mutect2, varscan2
- EFHD2 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.048); catalogued as COSV65658131; called by muse, mutect2
- EGFLAM | c.1988C>T p.S663F | Missense Mutation (SNP) | VAF 70/201 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59307413; called by muse, mutect2, varscan2
- EIF3A | c.1996C>T p.P666S | Missense Mutation (SNP) | VAF 18/28 reads (64%) | SIFT tolerated (0.34); PolyPhen benign (0.196); catalogued as COSV64961920; called by muse, mutect2, varscan2
- ELF2 | c.363T>G p.F121L (on ENST00000379550 / NM_001331036.2; = p.F61L on NM_006874.4) | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV99642491; called by muse, mutect2, varscan2
- ENAM | c.1312G>A p.E438K | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.767); catalogued as COSV68536338; called by muse, mutect2, varscan2
- ENPP4 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 44/130 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as COSV58088607; called by muse, mutect2, varscan2
- EPB41L2 | c.921T>A p.D307E | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61356832; called by muse, mutect2, varscan2
- EPB41L4A | c.1631C>T p.P544L | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54873564; called by muse, mutect2, varscan2
- EPHA7 | c.2714G>A p.G905E | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0.158); catalogued as COSV65177961; called by muse, mutect2, varscan2
- EPHA7 | c.146C>T p.S49F | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV65168659; called by muse, mutect2, varscan2
- EPHA8 | c.2452G>A p.A818T | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as rs939029576, COSV51274360; called by muse, mutect2, varscan2
- EPRS1 | c.2672C>T p.S891F | Missense Mutation (SNP) | VAF 72/189 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as rs1293805075, COSV65099965; called by muse, mutect2, varscan2
- EPS8L3 | c.300T>G p.N100K | Missense Mutation (SNP) | VAF 171/307 reads (56%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV62609828; called by muse, mutect2, varscan2
- ERBB4 | c.337G>A p.D113N | Missense Mutation (SNP) | VAF 42/59 reads (71%) | SIFT tolerated (0.54); PolyPhen benign (0.115); catalogued as COSV53537236; called by muse, mutect2, varscan2
- ERF | c.854C>T p.P285L | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1317815490, COSV55896548; called by muse, mutect2, varscan2
- ERG | c.660A>T p.Q220H | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.758); catalogued as COSV55734716; called by muse, mutect2, varscan2
- ERICH3 | c.364C>T p.P122S | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1394676449, COSV58610741; called by muse, mutect2, varscan2
- ERV3-1 | c.331C>T p.P111S | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs1356542926, COSV51428347; called by muse, mutect2, varscan2
- EVPL | c.4189G>A p.E1397K | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as rs751540924, COSV56912812; called by muse, mutect2, varscan2
- EXOSC10 | c.125C>T p.S42F | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.498); catalogued as COSV58666295; called by muse, mutect2, varscan2
- EYA2 | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 38/141 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV57946154; called by muse, mutect2, varscan2
- EYA4 | c.1123G>A p.E375K (on ENST00000531901 / NM_001301013.1; = p.E369K on NM_004100.5) | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.176); catalogued as COSV62055386; called by muse, mutect2, varscan2
- F11 | c.575C>T p.S192F | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53007726; called by muse, mutect2, varscan2
- FAM135B | c.1796G>A p.G599E | Missense Mutation (SNP) | VAF 34/162 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs745812863, COSV52735192; called by muse, varscan2
- FAM153A | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.188); catalogued as COSV100646905; called by mutect2, varscan2
- FAM83B | c.1663G>A p.E555K | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs868445452, COSV100174316, COSV60923782; called by muse, mutect2, varscan2
- FANCI | c.3322G>A p.G1108R (on ENST00000310775 / NM_001376911.1; = p.G1048R on NM_018193.3) | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV55529470; called by muse, mutect2, varscan2
- FAT3 | c.9139A>T p.I3047F | Missense Mutation (SNP) | VAF 78/472 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0.034); catalogued as COSV53133341; called by muse, mutect2, varscan2
- FAT3 | c.10970C>T p.S3657F | Missense Mutation (SNP) | VAF 170/512 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV53133364, COSV53184206; called by muse, mutect2, varscan2
- FBLN1 | c.952C>T p.P318S | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.665); catalogued as rs113064196, COSV53049518; called by muse, mutect2, varscan2
- FBLN5 | c.1319G>A p.R440Q | Missense Mutation (SNP) | VAF 48/95 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as rs755330702, COSV50905157; called by muse, mutect2, varscan2
- FBXO40 | c.419C>T p.S140F | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs267599566, COSV57525227; called by muse, mutect2, varscan2
- FBXO42 | c.335C>T p.P112L | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as COSV65046139; called by muse, mutect2, varscan2
- FCGBP | c.8042C>T p.P2681L | Missense Mutation (SNP) | VAF 22/231 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99662987; called by muse, mutect2
- FCRL5 | c.1772G>A p.R591K | Missense Mutation (SNP) | VAF 50/132 reads (38%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.914); catalogued as COSV62516363; called by muse, mutect2, varscan2
- FCRL6 | c.1251G>A p.M417I | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV58939881, COSV58941606; called by muse, mutect2, varscan2
- FER1L6 | c.3175C>T p.P1059S | Missense Mutation (SNP) | VAF 54/146 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67550031, COSV67551003; called by muse, mutect2, varscan2
- FLG | c.4391G>A p.G1464E | Missense Mutation (SNP) | VAF 89/408 reads (22%) | SIFT tolerated (1); PolyPhen possibly damaging (0.746); catalogued as COSV64243483; called by muse, mutect2, varscan2
- FLG | c.2911C>T p.R971C | Missense Mutation (SNP) | VAF 195/520 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as COSV64243257, COSV64247172; called by muse, mutect2, varscan2
- FLT1 | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1473309404, COSV56725918; called by muse, mutect2, varscan2
- FMN2 | c.2228C>T p.S743L | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs1397813836, COSV60424392; called by muse, mutect2
- FMN2 | c.3946G>A p.E1316K | Missense Mutation (SNP) | VAF 52/150 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.841); catalogued as COSV60428047; called by muse, mutect2, varscan2
- FNDC1 | c.4832T>C p.V1611A | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.318); catalogued as rs1374105596, COSV51941535; called by muse, mutect2
- FOCAD | c.5045T>C p.V1682A | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.442); catalogued as COSV58102394; called by muse, mutect2, varscan2
- FOLH1 | c.1786G>A p.D596N | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV57051515; called by muse, mutect2, varscan2
- FRAS1 | c.8011G>A p.E2671K | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760160124, COSV53588710; called by muse, mutect2
- FRAS1 | c.10546C>T p.Q3516* | Nonsense Mutation (SNP) | VAF 13/51 reads (25%) | catalogued as COSV99347876; called by muse, mutect2, varscan2
- FREM1 | c.2468G>A p.G823E | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66525859; called by muse, mutect2, varscan2
- FREM2 | c.1414G>A p.D472N | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779885596, COSV54842373; called by muse, mutect2, varscan2
- FRS3 | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 36/147 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV52485406; called by muse, mutect2, varscan2
- FUT7 | c.1024G>A p.A342T | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.41); PolyPhen benign (0.01); catalogued as COSV55803204; called by muse, varscan2
- FYB1 | c.128G>A p.G43E | Missense Mutation (SNP) | VAF 29/51 reads (57%) | SIFT tolerated (0.21); PolyPhen benign (0.092); catalogued as COSV60949717; called by muse, mutect2, varscan2
- GABRA3 | c.983C>T p.S328F | Missense Mutation (SNP) | VAF 28/42 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs1405808499, COSV64795525; called by muse, mutect2, varscan2
- GALNT12 | c.374G>A p.C125Y | Missense Mutation (SNP) | VAF 29/49 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66663043; called by muse, mutect2, varscan2
- GALNT17 | c.955C>T p.P319S | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV61169761; called by muse, mutect2, varscan2
- GAS2 | c.353C>T p.S118F | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT tolerated (0.7); PolyPhen benign (0.392); catalogued as rs760338425, COSV53409055; called by muse, mutect2, varscan2
- GATA3 | c.1220C>T p.S407L | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT tolerated (0.32); PolyPhen benign (0.054); catalogued as rs752977342, COSV60515966, COSV60516876; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GBX1 | c.526C>T p.P176S | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.066); catalogued as COSV52547981; called by muse, mutect2, varscan2
- GCM2 | c.701C>T p.S234F | Missense Mutation (SNP) | VAF 57/133 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.618); catalogued as COSV65275767; called by muse, mutect2, varscan2
- GCOM1 | c.202C>T p.P68S | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.172); catalogued as COSV51088228; called by muse, mutect2, varscan2
- GEMIN4 | c.1273T>A p.F425I | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56746394; called by muse, mutect2, varscan2
- GIMAP6 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 42/168 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.273); catalogued as rs765053253, COSV61033006; called by muse, mutect2, varscan2
- GIMAP7 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs755681348, COSV57959710; called by muse, mutect2, varscan2
- GIMAP8 | c.1867G>A p.D623N | Missense Mutation (SNP) | VAF 45/128 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV56232371; called by muse, mutect2, varscan2
- GJA5 | c.97C>T p.R33C | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54782951; called by muse, mutect2, varscan2
- GJB6 | c.495G>A p.W165* | Nonsense Mutation (SNP) | VAF 13/32 reads (41%) | catalogued as COSV53832860; called by muse, mutect2, varscan2
- GML | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.744); catalogued as COSV55277715; called by muse, mutect2, varscan2
- GNA12 | c.718C>T p.Q240* | Nonsense Mutation (SNP) | VAF 123/223 reads (55%) | catalogued as COSV51742618; called by muse, mutect2, varscan2
- GNAS | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.916); catalogued as COSV58338955; called by muse, mutect2
- GNG2 | c.178C>T p.P60S | Missense Mutation (SNP) | VAF 41/139 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58914412; called by muse, mutect2, varscan2
- GOLGA4 | c.2929C>T p.Q977* | Nonsense Mutation (SNP) | VAF 42/133 reads (32%) | catalogued as COSV62711699; called by muse, mutect2, varscan2
- GON4L | c.1202C>T p.P401L | Missense Mutation (SNP) | VAF 35/178 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55196661; called by muse, mutect2, varscan2
- GPATCH4 | c.349-1G>A p.X117_splice | Splice Site (SNP) | VAF 78/203 reads (38%) | catalogued as COSV58039848, COSV58040573; called by muse, mutect2, varscan2
- GPR108 | c.622C>T p.H208Y | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs780817351, COSV51184427; called by muse, mutect2, varscan2
- GPR50 | c.1840G>A p.E614K | Missense Mutation (SNP) | VAF 45/59 reads (76%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.124); catalogued as COSV54439501, COSV54440362; called by muse, mutect2, varscan2
- GPRC6A | c.1607G>A p.R536K | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV59953909; called by muse, mutect2, varscan2
- GRAMD4 | c.491C>T p.S164L | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0.011); catalogued as rs564439460, COSV63031019; called by muse, mutect2, varscan2
- GRK7 | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs781303819, COSV53823710; called by muse, varscan2
- GRXCR1 | c.590C>T p.S197F | Missense Mutation (SNP) | VAF 138/436 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV67670672; called by muse, mutect2, varscan2
- GSDMB | c.762G>A p.M254I (on ENST00000418519 / NM_001165958.1; = p.M232I on NM_018530.2) | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV58781397; called by muse, mutect2, varscan2
- GTF2B | c.743G>A p.R248K | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.382); catalogued as COSV65137179, COSV65137355; called by muse, mutect2, varscan2
- H2AB1 | c.308A>G p.N103S | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV100371463; called by mutect2, varscan2
- HAPLN4 | c.265G>A p.V89M | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.688); catalogued as COSV99363574; called by muse, mutect2, varscan2
- HCRTR2 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as rs766006062, COSV63793711, COSV99057010; called by muse, mutect2, varscan2
- HDAC11 | c.506T>G p.V169G | Missense Mutation (SNP) | VAF 40/142 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV55473747; called by muse, mutect2, varscan2
- HECTD1 | c.1597C>T p.Q533* | Nonsense Mutation (SNP) | VAF 67/228 reads (29%) | catalogued as COSV67947372; called by muse, mutect2, varscan2
- HERC2 | c.13275C>T p.V4425= | Splice Region (SNP) | VAF 17/38 reads (45%) | catalogued as COSV55331496; called by muse, mutect2, varscan2
- HEXD | c.1062-6C>T | Splice Region (SNP) | VAF 59/195 reads (30%) | catalogued as COSV60064667; called by muse, mutect2, varscan2
- HEY2 | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 58/200 reads (29%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.601); catalogued as COSV64240129; called by muse, mutect2, varscan2
- HIVEP1 | c.1492G>T p.E498* | Nonsense Mutation (SNP) | VAF 27/66 reads (41%) | catalogued as COSV65102941; called by muse, mutect2, varscan2
- HNF4G | c.902A>T p.Q301L (on ENST00000354370 / NM_001330561.2; = p.Q348L on NM_004133.5) | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.257); catalogued as COSV62970320; called by muse, mutect2, varscan2
- HOMEZ | c.623C>T p.P208L | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV62537397; called by muse, mutect2, varscan2
- HSF5 | c.760C>T p.P254S | Missense Mutation (SNP) | VAF 54/174 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.734); catalogued as rs868707951, COSV60416173; called by muse, mutect2, varscan2
- HSP90B1 | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as rs1293862440, COSV55356284; called by muse, mutect2
- HTR2C | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 41/77 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52200883, COSV52216790; called by muse, mutect2, varscan2
- HTRA1 | c.623T>C p.I208T | Missense Mutation (SNP) | VAF 47/101 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64564556; called by muse, mutect2, varscan2
- HUWE1 | c.4429C>T p.R1477C | Missense Mutation (SNP) | VAF 64/110 reads (58%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as COSV53350942; called by muse, mutect2, varscan2
- HYDIN | c.1111G>A p.D371N | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55477888; called by muse, mutect2, varscan2
- ICA1L | c.31G>A p.D11N | Missense Mutation (SNP) | VAF 306/467 reads (66%) | SIFT tolerated (0.13); PolyPhen benign (0.199); catalogued as COSV64173855; called by muse, mutect2, varscan2
- IDO2 | c.979G>A p.D327N (on ENST00000389060; = p.D340N on NM_194294.2) | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.045); catalogued as COSV58426600; called by muse, mutect2, varscan2
- IFNB1 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 55/175 reads (31%) | SIFT tolerated (0.74); PolyPhen benign (0.024); catalogued as COSV66525537; called by muse, mutect2, varscan2
- IGF2BP3 | c.320T>G p.V107G | Missense Mutation (SNP) | VAF 64/123 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV51687703; called by muse, mutect2, varscan2
- IGF2R | c.4954T>G p.C1652G | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63630325; called by muse, mutect2, varscan2
- IGHG1 | c.628G>A p.A210T | Missense Mutation (SNP) | VAF 116/277 reads (42%) | SIFT tolerated (0.45); PolyPhen benign (0.408); catalogued as rs781478879; called by muse, mutect2, varscan2
- IGHV3-13 | c.115C>T p.L39F | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as rs1555437247; called by muse, mutect2, varscan2
- IMPG1 | c.1917G>A p.M639I | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.046); catalogued as COSV64056872; called by muse, mutect2, varscan2
- INTS14 | c.733A>T p.K245* (on ENST00000313182 / NM_001366360.2; = p.K166* on NM_001136043.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 12/60 reads (20%) | catalogued as COSV57527666; called by muse, mutect2, varscan2
- ISL2 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV51958208; called by muse, mutect2, varscan2
- ITGA11 | c.2776G>A p.E926K | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.013); catalogued as rs751916986, COSV59875813, COSV59879199; called by muse, mutect2, varscan2
- ITGA2 | c.3161C>T p.S1054F | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.309); catalogued as COSV56862360; called by muse, mutect2, varscan2
- ITGAM | c.2498C>T p.S833F (on ENST00000648685 / NM_001145808.2; = p.S832F on NM_000632.4) | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.059); catalogued as COSV54938745; called by muse, mutect2, varscan2
- ITIH1 | c.1855G>A p.G619S | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.511); catalogued as rs751817615, COSV56256302; called by muse, mutect2, varscan2
- JAML | c.689G>A p.G230E (on ENST00000356289 / NM_001098526.2; = p.G220E on NM_153206.3) | Missense Mutation (SNP) | VAF 66/151 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52628334; called by muse, mutect2, varscan2
- JCAD | c.3529G>C p.D1177H | Missense Mutation (SNP) | VAF 62/127 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.562); catalogued as COSV64760438; called by muse, mutect2, varscan2
- KCNA1 | c.790C>T p.P264S | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66838955; called by muse, mutect2, varscan2
- KCNA1 | c.791C>T p.P264L | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66838962; called by muse, mutect2, varscan2
- KCNC4 | c.1849C>T p.Q617* | Nonsense Mutation (SNP) | VAF 18/46 reads (39%) | catalogued as COSV100873559, COSV63925565; called by muse, mutect2
- KCNH4 | c.2561C>T p.P854L | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV52918847; called by muse, mutect2, varscan2
- KCNH5 | c.2707G>A p.E903K | Missense Mutation (SNP) | VAF 56/151 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.23); catalogued as rs765947232, COSV59764081; called by muse, mutect2, varscan2
- KCNH8 | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 89/232 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60460404; called by muse, mutect2, varscan2
- KCNQ1 | c.1151C>T p.A384V | Missense Mutation (SNP) | VAF 95/344 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.086); catalogued as COSV50115362; called by muse, mutect2, varscan2
- KCNS3 | c.1144G>A p.A382T | Missense Mutation (SNP) | VAF 52/79 reads (66%) | SIFT tolerated (0.14); PolyPhen benign (0.091); catalogued as COSV58407785; called by muse, mutect2, varscan2
- KCNT1 | c.918G>A p.W306* (on ENST00000488444; = p.W325* on NM_020822.3) | Nonsense Mutation (SNP) | VAF 19/40 reads (48%) | catalogued as COSV53704454; called by muse, mutect2, varscan2
- KCNT2 | c.2940G>A p.W980* | Nonsense Mutation (SNP) | VAF 43/142 reads (30%) | catalogued as COSV54072816, COSV54088810; called by muse, mutect2, varscan2
- KCNU1 | c.2359C>T p.H787Y | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.454); catalogued as COSV67757434; called by muse, mutect2, varscan2
- KDM2B | c.3383C>T p.S1128F | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV65642504; called by muse, mutect2, varscan2
- KERA | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.83); PolyPhen benign (0.03); catalogued as COSV57131005, COSV99899258; called by muse, mutect2, varscan2
- KIAA0319 | c.2912G>A p.G971E | Missense Mutation (SNP) | VAF 83/380 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.889); catalogued as COSV65499701; called by muse, mutect2, varscan2
- KIAA0319 | c.1261A>C p.N421H | Missense Mutation (SNP) | VAF 64/295 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV65499710; called by muse, mutect2, varscan2
- KIAA1217 | c.3299C>T p.P1100L | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.327); catalogued as COSV56818886; called by muse, mutect2, varscan2
- KIAA1614 | c.214G>A p.V72I | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as rs754444210, COSV62553068; called by muse, mutect2
- KIF13A | c.971C>T p.S324F | Missense Mutation (SNP) | VAF 194/332 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as COSV52456225; called by muse, mutect2, varscan2
- KIF1A | c.2627A>C p.K876T | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.94); catalogued as COSV57493466; called by muse, mutect2, varscan2
- KIF1C | c.2794C>T p.P932S | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as rs777872350, COSV57905268; called by muse, mutect2, varscan2
- KIF21B | c.2654C>T p.P885L | Missense Mutation (SNP) | VAF 74/178 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV59760529; called by muse, mutect2, varscan2
- KIF23 | c.2200C>T p.P734S | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs559197892, COSV52978462; called by muse, mutect2, varscan2
- KIF4B | c.1549C>T p.L517F | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.362); catalogued as rs769646905, COSV70530149; called by muse, mutect2, varscan2
- KIN | c.511A>G p.K171E | Missense Mutation (SNP) | VAF 81/176 reads (46%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.492); catalogued as COSV65430880; called by muse, mutect2, varscan2
- KLHL13 | c.494A>G p.Q165R | Missense Mutation (SNP) | VAF 44/59 reads (75%) | SIFT tolerated (0.12); PolyPhen benign (0.221); catalogued as COSV53249589; called by muse, mutect2, varscan2
- KLHL36 | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.114); catalogued as COSV50720200; called by muse, mutect2, varscan2
- KLHL40 | c.1823T>G p.F608C | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT tolerated (0.94); PolyPhen benign (0.003); catalogued as COSV55135402; called by muse, mutect2, varscan2
- KLHL8 | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs144616595; called by muse, mutect2, varscan2
- KLK6 | c.454C>T p.P152S | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs201461622, COSV59566019; called by muse, mutect2, varscan2
- KLKB1 | c.106G>T p.V36L | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.045); catalogued as COSV52996793; called by muse, mutect2, varscan2
- KLKB1 | c.392T>G p.V131G | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.543); catalogued as COSV52996803; called by muse, mutect2, varscan2
- KMT2C | c.6827C>T p.P2276L | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs1445885320, COSV51457829; called by muse, mutect2, varscan2
- KPRP | c.527G>A p.G176E | Missense Mutation (SNP) | VAF 24/162 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.156); catalogued as rs867104936, COSV64221148; called by muse, mutect2, varscan2
- KRT5 | c.1432G>A p.E478K | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs267607438, CM095415, COSV52861607; ClinVar: not provided; called by muse, mutect2, varscan2
- KRT76 | c.1221G>A p.M407I | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.179); catalogued as rs868612460, COSV60119958; called by muse, mutect2, varscan2
- KRT78 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.227); catalogued as COSV58852273, COSV58852633; called by muse, mutect2, varscan2
- KRTAP10-6 | c.794C>T p.P265L | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.354); catalogued as COSV100551706; called by muse, mutect2, varscan2
- KRTAP10-6 | c.793C>T p.P265S | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.009); catalogued as rs1158572406, COSV100551708; called by muse, mutect2, varscan2
- KRTAP10-8 | c.701C>T p.S234F | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as COSV58166636; called by muse, mutect2, varscan2
- KRTAP12-1 | c.257G>A p.R86K | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs138110019, COSV59968152; called by muse, mutect2, varscan2
- L1TD1 | c.482C>T p.P161L | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as COSV63133645; called by muse, mutect2
- LAMA2 | c.4708G>A p.E1570K | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as rs1218997631, COSV70350896; called by muse, mutect2, varscan2
- LAMA4 | c.221C>T p.T74I | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.339); catalogued as COSV54570206; called by muse, mutect2, varscan2
- LAMA5 | c.8114T>G p.V2705G | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV53363474; called by muse, mutect2, varscan2
- LAMB2 | c.4876C>G p.R1626G | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as COSV100026128, COSV59730648, COSV59734923; called by muse, mutect2, varscan2
- LAMB3 | c.2836G>A p.D946N | Missense Mutation (SNP) | VAF 53/144 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as COSV50523195; called by muse, mutect2, varscan2
- LAMTOR2 | c.355C>T p.L119F | Missense Mutation (SNP) | VAF 71/235 reads (30%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as rs1198283062, COSV63108375; called by muse, mutect2, varscan2
- LASP1 | c.214C>T p.L72F | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV100530290; called by muse, mutect2, varscan2
- LBP | c.1005G>A p.M335I | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); catalogued as COSV54139036; called by muse, mutect2, varscan2
- LDB2 | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1277170300, COSV58765241, COSV58766021; called by muse, varscan2
- LGALS14 | c.53C>T p.S18L | Missense Mutation (SNP) | VAF 85/226 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.93); catalogued as rs150238702, COSV62372886; called by muse, mutect2, varscan2
- LGR6 | c.1826C>T p.T609I (on ENST00000367278 / NM_001017403.1; = p.T557I on NM_021636.3) | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV55160126; called by muse, mutect2, varscan2
- LGSN | c.1022G>A p.G341E | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65727635; called by muse, mutect2, varscan2
- LILRA2 | c.620C>T p.S207F | Missense Mutation (SNP) | VAF 52/257 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52193273, COSV52194642; called by muse, mutect2, varscan2
- LIN7A | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.722); catalogued as rs772890581, COSV54019429; called by muse, mutect2, varscan2
- LMX1B | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.678); catalogued as rs760853803, CD042603, COSV62740520; called by muse, mutect2
- LPAR2 | c.650G>T p.R217L | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as rs777696944, COSV52556575, COSV52557577; called by muse, mutect2, varscan2
- LRFN1 | c.1844C>T p.A615V | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.043); catalogued as COSV50462371; called by muse, mutect2, varscan2
- LRGUK | c.11C>T p.S4F | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); catalogued as COSV99603685; called by muse, varscan2
- LRP12 | c.905C>T p.T302I | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.575); catalogued as COSV52630459; called by muse, mutect2, varscan2
- LRP2 | c.11128G>A p.D3710N | Missense Mutation (SNP) | VAF 42/63 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55560061; called by muse, mutect2, varscan2
- LRP4 | c.1288C>T p.R430W | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.184); catalogued as rs140528156, COSV66136753; called by muse, mutect2, varscan2
- LRRC4C | c.891T>A p.H297Q | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.071); catalogued as COSV53429970; called by muse, mutect2, varscan2
- LRRK2 | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.57); PolyPhen benign (0.011); catalogued as rs201159244, COSV54158864; called by muse, mutect2, varscan2
- LTN1 | c.1969C>T p.P657S | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.857); catalogued as COSV63734190; called by muse, mutect2, varscan2
- LY6G6F | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 193/757 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs766054777, COSV101011700; called by muse, mutect2, varscan2
- LYAR | c.383C>T p.S128F | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); catalogued as COSV58642240; called by muse, mutect2, varscan2
- LYZL6 | c.310C>T p.P104S | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.207); catalogued as rs1366880300; called by muse, mutect2, varscan2
- MACF1 | c.5060C>T p.S1687F | Missense Mutation (SNP) | VAF 31/87 reads (36%) | catalogued as rs1396215555, COSV57129028; called by muse, mutect2, varscan2
- MACF1 | c.15964A>T p.N5322Y (on ENST00000372915; = p.N3255Y on NM_012090.5) | Missense Mutation (SNP) | VAF 16/51 reads (31%) | catalogued as COSV57129033; called by muse, mutect2, varscan2
- MADD | c.3980C>T p.A1327V | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.995); catalogued as COSV60625952; called by muse, mutect2, varscan2
- MAGEA12 | c.373C>T p.R125* | Nonsense Mutation (SNP) | VAF 50/83 reads (60%) | catalogued as COSV63294883, COSV63294966; called by muse, mutect2, varscan2
- MAGEE1 | c.881C>T p.T294I | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); catalogued as COSV100819234; called by muse, mutect2, varscan2
- MAMDC2 | c.1243C>T p.H415Y | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs867548987, COSV65857439; called by muse, mutect2, varscan2
- MAP10 | c.1720A>C p.K574Q | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.461); catalogued as COSV69364026; called by muse, varscan2
- MAP10 | c.1792G>A p.G598R | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.085); catalogued as COSV101406428; called by muse, varscan2
- MAP2K3 | c.50G>A p.G17E | Missense Mutation (SNP) | VAF 58/288 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0.067); catalogued as COSV57570976, COSV57573018; called by muse, mutect2, varscan2
- MAP6 | c.919G>A p.A307T | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV59076420; called by muse, mutect2, varscan2
- MARCHF1 | c.292C>T p.R98C (on ENST00000274056; = p.R81C on NM_017923.4) | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.055); catalogued as rs774218235, COSV99920175; called by muse, mutect2
- MAST1 | c.1563G>C p.M521I | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.04); catalogued as COSV52249312; called by muse, varscan2
- MDN1 | c.2576C>T p.S859F | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65524157; called by muse, mutect2, varscan2
- MEFV | c.568C>T p.P190S | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.75); PolyPhen benign (0.035); catalogued as COSV54825212; called by muse, varscan2
- MFSD3 | c.956-2A>C p.X319_splice | Splice Site (SNP) | VAF 20/50 reads (40%) | catalogued as COSV56741695; called by muse, mutect2, varscan2
- MGAM | c.2827G>A p.D943N | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs747835199, COSV101527358; called by muse, mutect2, varscan2
- MGAM | c.4540C>T p.P1514S | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV72073539; called by muse, mutect2, varscan2
- MIA3 | c.4294G>C p.D1432H | Missense Mutation (SNP) | VAF 198/520 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV60514569; called by muse, mutect2, varscan2
- MLIP | c.1207C>T p.L403F | Missense Mutation (SNP) | VAF 89/267 reads (33%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.733); catalogued as COSV51432272; called by muse, mutect2, varscan2
- MLXIP | c.1034C>T p.S345F | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV59836392; called by muse, mutect2
- MMP12 | c.1109C>T p.S370F | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.5); catalogued as rs868995352, COSV58259119, COSV58260360; called by muse, mutect2, varscan2
- MOG | c.61C>T p.L21F | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as rs1255064487, COSV65321389; called by muse, mutect2, varscan2
- MON1A | c.827C>T p.S276F | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1559492189, COSV56561360; called by muse, mutect2, varscan2
- MPND | c.1280G>A p.R427K | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs757859959, COSV99514966; called by muse, mutect2, varscan2
- MRGPRX1 | c.314C>T p.S105F | Missense Mutation (SNP) | VAF 48/321 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as COSV57105899; called by muse, mutect2, varscan2
- MRGPRX1 | c.131G>A p.G44E | Missense Mutation (SNP) | VAF 61/373 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV57106005; called by muse, mutect2, varscan2
- MROH2B | c.4063C>T p.H1355Y | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as COSV68180836; called by muse, mutect2, varscan2
- MROH7 | c.368C>T p.P123L | Missense Mutation (SNP) | VAF 47/165 reads (28%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.483); catalogued as rs184477025, COSV59874013; called by muse, mutect2, varscan2
- MSR1 | c.878G>A p.R293Q | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as rs370472553, COSV100027792; called by muse, mutect2, varscan2
- MTARC1 | c.734G>A p.G245E | Missense Mutation (SNP) | VAF 61/303 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV65055321, COSV65055410; called by muse, mutect2, varscan2
- MTFR1 | c.95C>T p.S32L | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs903374199, COSV50951059; called by muse, mutect2, varscan2
- MTMR3 | c.536C>T p.S179F | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as COSV60305930; called by muse, mutect2, varscan2
- MTNR1A | c.999G>A p.W333* | Nonsense Mutation (SNP) | VAF 55/148 reads (37%) | catalogued as COSV56156546; called by muse, mutect2, varscan2
- MUC16 | c.35105C>T p.S11702F | Missense Mutation (SNP) | VAF 51/139 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.181); catalogued as COSV67465435, COSV67476127; called by muse, mutect2, varscan2
- MUC16 | c.29862G>A p.M9954I | Missense Mutation (SNP) | VAF 106/357 reads (30%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.068); catalogued as COSV67476129, COSV67496215; called by muse, mutect2, varscan2
- MUC16 | c.23503G>A p.E7835K | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.192); catalogued as rs774892367, COSV67476132; called by muse, mutect2
- MUC16 | c.23060C>T p.P7687L | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV67450618; called by muse, mutect2, varscan2
- MUC16 | c.22129G>A p.D7377N | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as COSV67452419; called by muse, mutect2, varscan2
- MUC16 | c.5830G>A p.E1944K | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.801); catalogued as COSV67449320; called by muse, mutect2, varscan2
- MUC17 | c.3851C>T p.P1284L | Missense Mutation (SNP) | VAF 78/266 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV60293500; called by muse, mutect2, varscan2
- MUC17 | c.5230C>T p.P1744S | Missense Mutation (SNP) | VAF 107/373 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs1336352446, COSV60283155; called by muse, mutect2, varscan2
- MUC6 | c.2180G>A p.G727D | Missense Mutation (SNP) | VAF 81/233 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs373048568; called by muse, mutect2, varscan2
- MUC7 | c.584C>T p.P195L | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as COSV59218879; called by muse, varscan2
- MUSK | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 50/118 reads (42%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.946); catalogued as COSV51889548; called by muse, mutect2, varscan2
- MUTYH | c.767C>T p.S256F | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.71); PolyPhen benign (0.021); catalogued as rs1553127975, COSV58344472; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MXRA5 | c.4090G>A p.E1364K | Missense Mutation (SNP) | VAF 14/19 reads (74%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as rs1310840774, COSV54233872, COSV54240240; called by muse, mutect2, varscan2
- MYB | c.1561C>T p.P521S | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV57199352; called by muse, mutect2, varscan2
- MYBPC3 | c.3770A>G p.N1257S | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV57029595; called by muse, mutect2, varscan2
- MYH1 | c.4829G>A p.R1610K | Missense Mutation (SNP) | VAF 69/130 reads (53%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as COSV56851519; called by muse, mutect2, varscan2
- MYH4 | c.2335G>A p.E779K | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs776140827, COSV55116809; called by muse, mutect2, varscan2
- MYO15A | c.1034C>T p.P345L | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.104); catalogued as rs1182500342, COSV52759696; called by muse, varscan2
- MYO18B | c.5073G>A p.W1691* | Nonsense Mutation (SNP) | VAF 5/18 reads (28%) | catalogued as rs1462230628, COSV59139135; called by mutect2, varscan2
- MYO1F | c.1304C>T p.P435L | Missense Mutation (SNP) | VAF 102/286 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs773888828, COSV57793485; called by muse, mutect2, varscan2
- MYOCD | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 68/132 reads (52%) | SIFT tolerated (0.05); PolyPhen benign (0.05); catalogued as rs267604740, COSV58502220; called by muse, mutect2, varscan2
- NBN | c.1618C>T p.H540Y | Missense Mutation (SNP) | VAF 40/135 reads (30%) | SIFT tolerated (0.9); PolyPhen benign (0.001); catalogued as rs1554558393, COSV55374312, COSV55377442; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NCAM1 | c.1324C>T p.P442S (on ENST00000316851 / NM_181351.5; = p.P432S on NM_000615.7) | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57513191; called by muse, mutect2, varscan2
- NCOR2 | c.79C>A p.P27T | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.998); catalogued as rs1382579427, COSV100656759; called by muse, mutect2, varscan2
- NCR1 | c.751C>T p.H251Y | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0.073); catalogued as COSV52557251; called by muse, mutect2, varscan2
- NEDD4 | c.3488G>A p.R1163Q (on ENST00000508342 / NM_001284338.1; = p.R744Q on NM_006154.4) | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs777845396, COSV59063357; called by muse, mutect2, varscan2
- NEFM | c.2452G>A p.E818K | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated, low confidence (0.27); PolyPhen possibly damaging (0.815); catalogued as rs868506885, COSV55333041; called by muse, mutect2
- NEGR1 | c.740G>A p.G247D | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV60853628; called by muse, mutect2, varscan2
- NELFA | c.136G>A p.A46T (on ENST00000542778; = p.A35T on NM_005663.5) | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV100424651; called by muse, mutect2
- NETO1 | c.1480G>A p.E494K | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.015); catalogued as COSV55000806, COSV55014594; called by muse, mutect2, varscan2
- NEXN | c.1252G>A p.E418K | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.169); catalogued as COSV100330962; called by muse, mutect2, varscan2
- NGFR | c.185C>T p.T62I | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50802773; called by muse, mutect2, varscan2
- NICN1 | c.49C>T p.Q17* | Nonsense Mutation (SNP) | VAF 17/39 reads (44%) | catalogued as COSV56474920; called by muse, mutect2, varscan2
- NLRP4 | c.561T>A p.Y187* | Nonsense Mutation (SNP) | VAF 50/149 reads (34%) | catalogued as COSV56716836; called by muse, mutect2, varscan2
- NLRP4 | c.1537G>A p.E513K | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV56716852; called by muse, mutect2, varscan2
- NLRP8 | c.1180C>T p.R394W | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs766183456, COSV52589819; called by muse, mutect2, varscan2
- NOC4L | c.1382C>T p.S461F | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV57957591; called by muse, mutect2, varscan2
- NOMO1 | c.2782C>T p.P928S | Missense Mutation (SNP) | VAF 44/206 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.79); catalogued as COSV55059644; called by muse, mutect2, varscan2
- NPBWR2 | c.859G>A p.D287N | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs1462916748, COSV63899806; called by muse, mutect2, varscan2
- NPPB | c.118A>G p.T40A | Missense Mutation (SNP) | VAF 55/154 reads (36%) | SIFT tolerated (0.83); PolyPhen benign (0.264); catalogued as COSV64687688; called by muse, mutect2, varscan2
- NR2F1 | c.527G>A p.G176E | Missense Mutation (SNP) | VAF 48/78 reads (62%) | SIFT deleterious (0.05); PolyPhen benign (0.164); catalogued as COSV59069209; called by muse, mutect2, varscan2
- NR2F1 | c.1174C>T p.R392C | Missense Mutation (SNP) | VAF 61/109 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59070328; called by muse, mutect2, varscan2
- NRAP | c.2112A>C p.E704D (on ENST00000359988 / NM_001322945.2; = p.E669D on NM_006175.4) | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.194); catalogued as COSV63491914; called by muse, mutect2, varscan2
- NRP1 | c.1019G>A p.G340E | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99587651; called by muse, mutect2, varscan2
- NUP107 | c.2759G>A p.G920E | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99971484; called by muse, mutect2, varscan2
- NUP42 | c.955C>G p.L319V | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.037); catalogued as COSV51730307; called by muse, mutect2, varscan2
- NUTM1 | c.1547G>A p.G516E | Missense Mutation (SNP) | VAF 54/139 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.276); catalogued as COSV59217548; called by muse, mutect2, varscan2
- OAF | c.808C>T p.P270S | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.053); catalogued as COSV61109494; called by muse, mutect2, varscan2
- OBSCN | c.13888C>T p.P4630S | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT tolerated (0.5); PolyPhen benign (0.009); catalogued as rs747702863, COSV99471842; called by muse, varscan2
- OIT3 | c.1333G>A p.D445N | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.999); catalogued as rs144807491; called by muse, varscan2
- OPN4 | c.956C>T p.A319V | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.25); catalogued as rs555049946, COSV54117272; called by muse, mutect2, varscan2
- OR10J5 | c.803A>C p.E268A | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.403); catalogued as COSV58386626; called by muse, mutect2, varscan2
- OR10K2 | c.824C>T p.S275L | Missense Mutation (SNP) | VAF 68/174 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59221735; called by muse, mutect2, varscan2
- OR10X1 | c.563A>G p.N188S | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs1429912410, COSV63767552; called by muse, mutect2, varscan2
- OR10X1 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 36/218 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs1184922903, COSV63766973; called by muse, mutect2, varscan2
- OR11H12 | c.409C>T p.Q137* | Nonsense Mutation (SNP) | VAF 29/212 reads (14%) | catalogued as COSV101612449; called by muse, mutect2, varscan2
- OR12D3 | c.737T>G p.V246G | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV65828722; called by muse, mutect2, varscan2
- OR13C3 | c.902A>T p.E301V | Missense Mutation (SNP) | VAF 42/66 reads (64%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.009); catalogued as COSV66165987; called by muse, mutect2, varscan2
- OR13C9 | c.555G>A p.M185I | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV52240833; called by muse, mutect2, varscan2
- OR13G1 | c.890G>A p.G297E | Missense Mutation (SNP) | VAF 32/157 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as COSV62944551; called by muse, mutect2, varscan2
- OR13G1 | c.331C>T p.L111F | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); catalogued as rs267598477, COSV100687222, COSV62944560; called by muse, mutect2, varscan2
- OR2A5 | c.118G>A p.G40R | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as COSV101278653, COSV101278869; called by muse, mutect2, varscan2
- OR2A5 | c.119G>A p.G40E | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.12); catalogued as COSV68738894; called by muse, mutect2, varscan2
- OR2A5 | c.351G>A p.M117I | Missense Mutation (SNP) | VAF 46/174 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1036675053, COSV68738879; called by muse, mutect2, varscan2
- OR2B2 | c.889G>A p.V297I | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as rs1228219432, COSV57580052; called by muse, mutect2, varscan2
- OR2B3 | c.728C>T p.S243F | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65850766; called by muse, mutect2, varscan2
- OR2G6 | c.800C>T p.S267F | Missense Mutation (SNP) | VAF 33/166 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.081); catalogued as rs867396066, COSV100598361, COSV58574999; called by muse, mutect2, varscan2
- OR2J3 | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 71/255 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as COSV65848780; called by muse, mutect2, varscan2
- OR2J3 | c.586C>T p.H196Y | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as COSV65849261; called by muse, mutect2, varscan2
- OR2T1 | c.316C>T p.L106F | Missense Mutation (SNP) | VAF 45/220 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.05); catalogued as rs764143289, COSV63542309, COSV63542989; called by muse, mutect2, varscan2
- OR4A5 | c.736C>T p.L246F | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.739); catalogued as rs146541729; called by muse, mutect2, varscan2
- OR4C3 | c.53A>G p.N18S | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.099); catalogued as COSV60587455; called by muse, varscan2
- OR4C46 | c.257G>A p.G86E | Missense Mutation (SNP) | VAF 43/146 reads (29%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs763866366, COSV60220118; called by muse, mutect2, varscan2
- OR4D11 | c.597G>A p.M199I | Missense Mutation (SNP) | VAF 56/166 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.098); catalogued as COSV57584852; called by muse, mutect2, varscan2
- OR4K14 | c.704C>T p.S235F | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.685); catalogued as COSV59293227; called by muse, mutect2, varscan2
- OR4K2 | c.208G>A p.D70N | Missense Mutation (SNP) | VAF 50/261 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.167); catalogued as rs267603912, COSV53850238; called by muse, mutect2, varscan2
- OR4N2 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 72/350 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs866280852, COSV60050102; called by muse, mutect2, varscan2
- OR51E1 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 50/127 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as COSV67809520, COSV67810482; called by muse, varscan2
- OR51G1 | c.80G>A p.G27D | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0.333); catalogued as rs762936228, COSV58969725; called by muse, mutect2, varscan2
- OR51I2 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as rs867120171, COSV58298078; called by muse, mutect2, varscan2
- OR51Q1 | c.823C>T p.H275Y | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV56178510; called by muse, mutect2, varscan2
- OR51T1 | c.593G>A p.S198N | Missense Mutation (SNP) | VAF 44/141 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.022); catalogued as COSV59026367; called by muse, mutect2, varscan2
- OR52E6 | c.688C>T p.P230S | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.439); catalogued as COSV61432480; called by muse, mutect2, varscan2
- OR56A4 | c.791C>T p.S264F | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.997); catalogued as COSV58111027; called by muse, mutect2
- OR5AK2 | c.847C>T p.P283S | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58804760; called by muse, mutect2, varscan2
- OR5AP2 | c.504G>A p.M168I | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as rs1422310376, COSV57257385; called by muse, mutect2, varscan2
- OR5B12 | c.710C>T p.S237F | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.521); catalogued as rs773515302, COSV56905243, COSV56905516; called by muse, mutect2, varscan2
- OR5B2 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as rs267603027, COSV56908754; called by muse, mutect2, varscan2
- OR5M11 | c.329A>C p.E110A | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV73141912; called by muse, mutect2, varscan2
- OR6C4 | c.160C>T p.Q54* | Nonsense Mutation (SNP) | VAF 48/179 reads (27%) | catalogued as COSV67793077; called by muse, mutect2, varscan2
- OR6C75 | c.25G>A p.D9N | Missense Mutation (SNP) | VAF 49/142 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV58552636; called by muse, mutect2, varscan2
- OR6N1 | c.482C>T p.S161F | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs748135010, COSV58648787; called by muse, mutect2, varscan2
- OR6X1 | c.872G>A p.R291K | Missense Mutation (SNP) | VAF 63/142 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as COSV60010003; called by muse, mutect2, varscan2
- OR8A1 | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.272); catalogued as COSV52509068; called by muse, mutect2, varscan2
- OR8B4 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0.007); catalogued as rs1330834383, COSV62069535; called by muse, mutect2, varscan2
- OR8G1 | c.704C>T p.S235F | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.068); catalogued as rs756830557, COSV58381844; called by muse, mutect2, varscan2
- OVCH2 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as rs775042724, COSV71952666; called by muse, mutect2, varscan2
- P2RY10 | c.989G>A p.S330N | Missense Mutation (SNP) | VAF 51/72 reads (71%) | SIFT tolerated (0.11); PolyPhen benign (0.025); catalogued as rs200050350, COSV50682535, COSV50686087; called by muse, mutect2, varscan2
- P2RY8 | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV67177677; called by muse, mutect2, varscan2
- PACSIN2 | c.1294C>T p.R432W | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs746963305, COSV54319850; called by muse, mutect2, varscan2
- PADI3 | c.334C>T p.L112F | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.745); catalogued as COSV64934776; called by muse, mutect2, varscan2
- PAK5 | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868564987, COSV62019951; called by muse, mutect2, varscan2
- PAK5 | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 85/289 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.726); catalogued as rs1388617807, COSV62023006; called by muse, mutect2, varscan2
- PALLD | c.1771G>A p.E591K | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs772476893, COSV54984881; called by muse, mutect2, varscan2
- PAN3 | c.1556G>A p.C519Y | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV56704634; called by muse, mutect2, varscan2
- PAPPA2 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 45/207 reads (22%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.001); catalogued as rs866461390, COSV62773209, COSV62780685; called by muse, mutect2, varscan2
- PAPPA2 | c.4969C>T p.P1657S | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.15); catalogued as rs771415361, COSV100867721, COSV62801949; called by muse, mutect2, varscan2
- PARVB | c.340G>A p.D114N | Missense Mutation (SNP) | VAF 48/175 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58688309; called by muse, mutect2, varscan2
- PATL1 | c.1789G>C p.V597L | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.118); catalogued as COSV55690651; called by muse, mutect2, varscan2
- PBXIP1 | c.1831C>T p.R611W | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs751683861, COSV63777368; called by muse, mutect2, varscan2
- PCDH19 | c.2334G>T p.K778N (on ENST00000373034 / NM_001184880.2; = p.K731N on NM_020766.3) | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as COSV55265986; called by muse, mutect2, varscan2
- PCDHB2 | c.1511C>T p.S504F | Missense Mutation (SNP) | VAF 52/117 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV50585570; called by muse, mutect2, varscan2
- PCDHB4 | c.353G>A p.G118E | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.192); catalogued as rs531973251, COSV52023915; called by muse, mutect2, varscan2
- PCF11 | c.1091C>T p.S364L | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs758443668, COSV53533679; called by muse, mutect2, varscan2
- PCK2 | c.1147G>A p.D383N | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.139); catalogued as COSV53749495; called by muse, mutect2, varscan2
- PDE2A | c.1315G>A p.E439K | Missense Mutation (SNP) | VAF 116/346 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.705); catalogued as COSV57809356; called by muse, varscan2
- PDE3A | c.1064G>A p.G355D | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62976055; called by muse, mutect2, varscan2
- PDE6G | c.71G>A p.R24K | Missense Mutation (SNP) | VAF 49/147 reads (33%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.017); catalogued as COSV58507683; called by muse, mutect2, varscan2
- PDZD2 | c.1273C>T p.L425F | Missense Mutation (SNP) | VAF 50/160 reads (31%) | SIFT tolerated (0.63); PolyPhen benign (0.021); catalogued as COSV56862951; called by muse, mutect2, varscan2
- PDZRN3 | c.1982C>T p.P661L | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.057); catalogued as COSV55205415; called by muse, mutect2, varscan2
- PELI3 | c.1309C>T p.H437Y | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57857090; called by muse, mutect2, varscan2
- PEX6 | c.1027C>G p.R343G | Missense Mutation (SNP) | VAF 44/175 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.054); catalogued as COSV55101632, COSV55103925; called by muse, mutect2, varscan2
- PFDN2 | c.221T>G p.V74G | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV63509999; called by muse, mutect2, varscan2
- PFKFB2 | c.443C>T p.S148F | Missense Mutation (SNP) | VAF 13/45 reads (29%) | PolyPhen benign (0.013); catalogued as COSV65548674; called by muse, mutect2, varscan2
- PGLYRP4 | c.769C>T p.R257W | Missense Mutation (SNP) | VAF 54/144 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs142296774, COSV100668455; called by muse, varscan2
- PHF20L1 | c.2735G>A p.G912E | Missense Mutation (SNP) | VAF 45/147 reads (31%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.563); catalogued as COSV55194682; called by muse, mutect2, varscan2
- PIGR | c.542G>A p.G181D | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.527); catalogued as COSV62904432; called by muse, mutect2
- PIK3C2B | c.747G>T p.L249F | Missense Mutation (SNP) | VAF 86/477 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as COSV100914988; called by muse, mutect2, varscan2
- PIK3C2B | c.746T>G p.L249W | Missense Mutation (SNP) | VAF 85/487 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.219); catalogued as rs1178866585, COSV100914989; called by muse, mutect2, varscan2
- PIK3C2G | c.3475G>A p.E1159K (on ENST00000676171; = p.E1118K on NM_004570.5) | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.981); catalogued as COSV56815909; called by muse, mutect2, varscan2
- PITPNM2 | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54903342; called by muse, mutect2, varscan2
- PIWIL2 | c.439G>A p.G147R | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as COSV100769348, COSV63252350; called by muse, mutect2, varscan2
- PKHD1 | c.3730G>A p.E1244K | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as CM149115, COSV100581071, COSV61882957; called by muse, mutect2, varscan2
- PKHD1 | c.1901G>A p.G634D | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.89); PolyPhen benign (0.001); catalogued as COSV61882970; called by muse, mutect2, varscan2
- PKP2 | c.2182G>A p.E728K | Missense Mutation (SNP) | VAF 46/155 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV50734902; called by muse, mutect2, varscan2
- PKP2 | c.1880C>T p.S627F | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.442); catalogued as rs769817013, COSV50727422; called by muse, varscan2
- PKP2 | c.1381C>T p.H461Y | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.029); catalogued as COSV50734996; called by muse, mutect2, varscan2
- PLCB1 | c.1423G>A p.E475K | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as COSV62057749; called by muse, mutect2, varscan2
- PLCL2 | c.1781A>C p.Q594P (on ENST00000615277 / NM_001144382.2; = p.Q468P on NM_015184.5) | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.733); catalogued as COSV67623102; called by muse, mutect2, varscan2
- PLEKHG4 | c.502C>T p.P168S | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV64613268; called by muse, mutect2, varscan2
- PLEKHG6 | c.1309C>T p.L437F | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.741); catalogued as COSV50603359; called by muse, mutect2, varscan2
- PNPLA1 | c.1319G>A p.R440Q (on ENST00000394571 / NM_001374623.1; = p.R345Q on NM_173676.2) | Missense Mutation (SNP) | VAF 49/180 reads (27%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as rs144648025; called by muse, mutect2, varscan2
- PNPLA8 | c.1219C>T p.P407S | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.543); catalogued as COSV57553396; called by muse, mutect2, varscan2
- POF1B | c.1084G>A p.D362N | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); catalogued as COSV53136135; called by muse, mutect2, varscan2
- POTED | c.387G>A p.M129I | Missense Mutation (SNP) | VAF 33/46 reads (72%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV55049326; called by muse, mutect2, varscan2
- POU6F2 | c.286C>T p.L96F | Missense Mutation (SNP) | VAF 36/279 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV68875959; called by muse, mutect2, varscan2
- POU6F2 | c.539A>C p.Q180P | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.282); catalogued as COSV68875965; called by muse, mutect2, varscan2
- POU6F2 | c.857C>T p.S286L | Missense Mutation (SNP) | VAF 70/124 reads (56%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.227); catalogued as COSV68872464, COSV68875972; called by muse, mutect2, varscan2
- PPEF2 | c.1381C>T p.R461* | Nonsense Mutation (SNP) | VAF 33/106 reads (31%) | catalogued as rs781170131, COSV54423706; called by muse, varscan2
- PPP1R36 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 93/240 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV53902758; called by muse, mutect2, varscan2
- PRB2 | c.238G>A p.G80R | Missense Mutation (SNP) | VAF 94/400 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.07); catalogued as COSV66982502, COSV66983512; called by muse, mutect2, varscan2
- PRB4 | c.443G>A p.G148E | Missense Mutation (SNP) | VAF 80/300 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.022); catalogued as rs865985353, COSV54397886; called by muse, varscan2
- PRKCG | c.577G>A p.D193N | Missense Mutation (SNP) | VAF 45/158 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as COSV54729266; called by muse, mutect2, varscan2
- PRMT8 | c.709C>T p.H237Y | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV54215845; called by muse, mutect2, varscan2
- PROKR2 | c.1073G>A p.G358E | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.209); catalogued as COSV54087427; called by muse, mutect2, varscan2
- PRX | c.1396C>T p.P466S | Missense Mutation (SNP) | VAF 61/178 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV52531115; called by muse, varscan2
- PSG3 | c.708C>T p.L236= | Splice Region (SNP) | VAF 118/352 reads (34%) | catalogued as COSV59505221; called by muse, mutect2, varscan2
- PSG3 | c.137C>T p.S46F | Missense Mutation (SNP) | VAF 57/221 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as COSV59503996; called by muse, mutect2, varscan2
- PTCHD4 | c.857C>T p.T286I | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as COSV100259915; called by muse, mutect2, varscan2
- PTGFR | c.673A>T p.I225F | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.399); catalogued as COSV66115638, COSV66115875; called by muse, mutect2, varscan2
- PTPRD | c.1682G>A p.R561Q | Missense Mutation (SNP) | VAF 39/145 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.054); catalogued as rs757922864, COSV61929535; called by muse, mutect2, varscan2
- PTPRD | c.182G>A p.G61E | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs724159852, COSV61933093; called by muse, mutect2, varscan2
- PTPRO | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.026); catalogued as rs147697088; called by muse, mutect2, varscan2
- PXDNL | c.331C>T p.H111Y | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.106); catalogued as COSV100680958; called by muse, mutect2, varscan2
- PYGL | c.1258C>T p.P420S | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); catalogued as COSV53585526; called by muse, mutect2, varscan2
- PYHIN1 | c.689C>T p.S230F | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as COSV63721229; called by muse, mutect2, varscan2
- QKI | c.955C>T p.R319* | Nonsense Mutation (SNP) | VAF 12/48 reads (25%) | catalogued as COSV51696720; called by muse, mutect2, varscan2
- RAB27B | c.406G>A p.D136N | Missense Mutation (SNP) | VAF 43/144 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50495241; called by muse, mutect2, varscan2
- RAB3GAP2 | c.2582C>T p.S861F | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV62783312; called by muse, mutect2, varscan2
- RALGAPA1 | c.587C>T p.P196L | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.873); catalogued as rs1477149227, COSV99353059; called by muse, mutect2, varscan2
- RALGAPA1 | c.586C>T p.P196S | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.718); catalogued as COSV99353064; called by muse, mutect2, varscan2
- RANBP17 | c.1959T>G p.S653R | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as COSV66652714; called by muse, mutect2, varscan2
- RANBP17 | c.2303C>T p.P768L | Missense Mutation (SNP) | VAF 115/213 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV66652719; called by muse, mutect2, varscan2
- RAPGEF6 | c.3881C>T p.S1294F | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); catalogued as rs897613310, COSV57244041; called by muse, mutect2, varscan2
- RARRES2 | c.282G>A p.R94= | Splice Region (SNP) | VAF 36/93 reads (39%) | catalogued as COSV56231610; called by muse, mutect2, varscan2
- RASA3 | c.2360T>C p.V787A | Missense Mutation (SNP) | VAF 64/117 reads (55%) | SIFT tolerated (0.49); PolyPhen benign (0.313); catalogued as COSV61869117; called by muse, mutect2, varscan2
- RASSF5 | c.479C>T p.P160L | Missense Mutation (SNP) | VAF 33/225 reads (15%) | SIFT tolerated (0.65); PolyPhen benign (0.012); catalogued as COSV62426327; called by muse, mutect2, varscan2
- RBBP6 | c.1079C>T p.S360F | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.272); catalogued as COSV60506241; called by muse, mutect2, varscan2
- RBM14 | c.1868C>T p.S623L | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as rs768721278, COSV59559612; called by muse, mutect2, varscan2
- RCAN3 | c.677C>T p.P226L | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); catalogued as rs1305847446, COSV65558667; called by muse, mutect2, varscan2
- RDH10 | c.317C>T p.P106L | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.005); catalogued as COSV53583162; called by muse, mutect2, varscan2
- RGS18 | c.512A>C p.H171P | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.249); catalogued as COSV66508785; called by muse, mutect2, varscan2
- RGS22 | c.2534C>T p.P845L | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV62663882; called by muse, mutect2, varscan2
- RGS7 | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755007339, COSV58530073, COSV58530443; called by muse, mutect2, varscan2
- RGS7BP | c.457C>T p.R153* | Nonsense Mutation (SNP) | VAF 48/74 reads (65%) | catalogued as COSV61835503; called by muse, varscan2
- RHBDL1 | c.938G>A p.G313D (on ENST00000219551 / NM_001318733.2; = p.G248D on NM_001278720.2) | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53485087; called by muse, mutect2, varscan2
- RIMBP2 | c.2485G>A p.D829N | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.318); catalogued as COSV55476732; called by muse, mutect2, varscan2
- RIMS2 | c.4202G>A p.G1401E (on ENST00000666250 / NM_001348490.2; = p.G972E on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867105084, COSV51666954; called by muse, mutect2, varscan2
- RIOK1 | c.697G>A p.G233S | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV53572403; called by muse, mutect2
- RNASE9 | c.264G>A p.M88I | Missense Mutation (SNP) | VAF 47/148 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.039); catalogued as rs1168904770, COSV58880655; called by muse, mutect2, varscan2
- RNF111 | c.104G>A p.G35E | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.007); catalogued as COSV62087645; called by muse, mutect2, varscan2
- RNF17 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.073); catalogued as rs866976953, COSV55043744, COSV99692493; called by muse, mutect2, varscan2
- RNF214 | c.1483C>T p.Q495* | Nonsense Mutation (SNP) | VAF 91/163 reads (56%) | catalogued as COSV100327108, COSV56119705; called by muse, mutect2, varscan2
- RNF43 | c.1687C>T p.Q563* | Nonsense Mutation (SNP) | VAF 66/196 reads (34%) | catalogued as COSV68458889; called by muse, mutect2, varscan2
- RO60 | c.569C>A p.P190H | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66474158; called by muse, mutect2
- ROBO1 | c.2104C>T p.Q702* | Nonsense Mutation (SNP) | VAF 7/22 reads (32%) | catalogued as COSV71396166; called by muse, mutect2
- ROBO2 | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.964); catalogued as rs567065372, COSV59896989; called by muse, varscan2
- ROS1 | c.6146C>T p.P2049L | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV63854249; called by muse, mutect2, varscan2
- ROS1 | c.3844C>T p.P1282S | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs1052987141, COSV63857021; called by muse, mutect2, varscan2
- RP1 | c.1030G>A p.E344K | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.859); catalogued as COSV55120000; called by muse, mutect2, varscan2
- RP1 | c.2908G>A p.E970K | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV55117041; called by muse, mutect2, varscan2
- RP1L1 | c.6863C>T p.P2288L | Missense Mutation (SNP) | VAF 65/240 reads (27%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.766); catalogued as rs1311493056, COSV66756944; called by muse, mutect2, varscan2
- RP1L1 | c.3571G>A p.E1191K | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.097); catalogued as rs1207551571, COSV66753217; called by muse, mutect2
- RPH3A | c.2071G>A p.V691M (on ENST00000389385 / NM_001143854.2; = p.V687M on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as rs757433178, COSV66991802; called by muse, mutect2, varscan2
- RPTN | c.344G>A p.G115E | Missense Mutation (SNP) | VAF 145/369 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs866577758, COSV60166417; called by muse, mutect2, varscan2
- RRAS | c.599C>T p.P200L | Missense Mutation (SNP) | VAF 42/151 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.089); catalogued as rs761629413, COSV55868702; called by muse, varscan2
- RTL9 | c.941C>T p.S314F | Missense Mutation (SNP) | VAF 114/166 reads (69%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as COSV71825833; called by muse, mutect2, varscan2
- RYR1 | c.5326C>T p.H1776Y | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV62101740; called by muse, mutect2, varscan2
- RYR1 | c.5704G>A p.E1902K | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.158); catalogued as COSV62092694; called by muse, mutect2, varscan2
- RYR2 | c.5443G>A p.E1815K | Missense Mutation (SNP) | VAF 180/455 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as rs1294638169, COSV63657858; called by muse, mutect2, varscan2
- SACS | c.3674T>C p.L1225S | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.096); catalogued as rs959856535, COSV66542566; called by muse, mutect2, varscan2
- SAMD4A | c.1697G>A p.G566E | Missense Mutation (SNP) | VAF 57/170 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.536); catalogued as COSV51883581; called by muse, mutect2, varscan2
- SAMD9 | c.932C>T p.P311L | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101180276, COSV66076320; called by muse, mutect2, varscan2
- SAMD9L | c.1353G>A p.M451I | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV100560262, COSV59082829; called by muse, mutect2, varscan2
- SCN11A | c.4354C>T p.Q1452* | Nonsense Mutation (SNP) | VAF 14/41 reads (34%) | catalogued as COSV56572909; called by muse, mutect2, varscan2
- SCN11A | c.1403C>T p.S468F | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV56569043; called by muse, mutect2, varscan2
- SCN3A | c.3587G>A p.R1196Q | Missense Mutation (SNP) | VAF 89/131 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs767542222, COSV51807579; called by muse, mutect2, varscan2
- SCN5A | c.4937T>G p.L1646R (on ENST00000333535 / NM_198056.3; = p.L1645R on NM_000335.5) | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM141798, COSV61129385; called by muse, mutect2, varscan2
- SCN5A | c.2462C>T p.S821L | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as COSV61129404; called by muse, mutect2, varscan2
- SCYL3 | c.827A>T p.D276V | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV63046487; called by muse, mutect2, varscan2
- SDR16C5 | c.94C>T p.P32S | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.13); catalogued as rs755026565, COSV58127105; called by muse, mutect2, varscan2
- SEC14L2 | c.895C>T p.P299S | Missense Mutation (SNP) | VAF 40/140 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as COSV57240892; called by muse, mutect2, varscan2
- SEC14L5 | c.805C>T p.R269W | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778316449, COSV52039575; called by muse, mutect2, varscan2
- SEC31B | c.2605C>T p.P869S | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV64844853; called by muse, mutect2, varscan2
- SEL1L2 | c.1631G>A p.R544Q | Missense Mutation (SNP) | VAF 38/135 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs756873615, COSV53154198; called by muse, mutect2, varscan2
- SEMA3E | c.1598G>A p.R533Q | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs773304273, COSV57096799; called by muse, mutect2, varscan2
- SEPTIN6 | c.409C>T p.R137* | Nonsense Mutation (SNP) | VAF 30/46 reads (65%) | catalogued as COSV59715294; called by muse, varscan2
- SEPTIN9 | c.367G>T p.G123W (on ENST00000427177 / NM_001113491.2; = p.G105W on NM_006640.4) | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.642); catalogued as COSV100217412; called by muse, mutect2, varscan2
- SEPTIN9 | c.368G>A p.G123E (on ENST00000427177 / NM_001113491.2; = p.G105E on NM_006640.4) | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.05); catalogued as rs764722321, COSV100217417; called by muse, mutect2, varscan2
- SERPINA10 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV56228844; called by muse, mutect2, varscan2
- SERPINA11 | c.406A>C p.K136Q | Missense Mutation (SNP) | VAF 95/181 reads (52%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.786); catalogued as COSV58242232, COSV58242405; called by muse, mutect2, varscan2
- SERPINB3 | c.475A>T p.I159F | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52192459; called by muse, mutect2, varscan2
- SERPINC1 | c.1370G>A p.R457K | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs748251829, CM010773, COSV62929711; called by muse, mutect2, varscan2
- SERPING1 | c.551G>A p.G184E | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM004902, COSV53543000; called by muse, mutect2
- SETD1A | c.2961T>G p.D987E | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV52689481; called by muse, mutect2, varscan2
- SETX | c.80C>T p.S27F | Missense Mutation (SNP) | VAF 29/45 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); catalogued as rs374733340, COSV56382754; called by muse, mutect2, varscan2
- SFMBT2 | c.1966C>T p.H656Y | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.335); catalogued as COSV62811959; called by muse, mutect2, varscan2
- SGCZ | c.610C>T p.Q204* | Nonsense Mutation (SNP) | VAF 26/78 reads (33%) | catalogued as COSV101166522, COSV66013593; called by muse, mutect2, varscan2
- SIGLEC1 | c.1227C>T p.N409= | Splice Region (SNP) | VAF 18/47 reads (38%) | catalogued as rs143886579; called by muse, mutect2, varscan2
- SIGLEC10 | c.215C>T p.P72L | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.123); catalogued as COSV59480554; called by muse, mutect2, varscan2
- SIPA1L2 | c.4892C>T p.P1631L | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.055); catalogued as COSV53393331, COSV53397681; called by muse, mutect2, varscan2
- SIPA1L3 | c.3362C>T p.P1121L | Missense Mutation (SNP) | VAF 41/141 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as COSV55917809; called by muse, mutect2, varscan2
- SIX4 | c.1888C>T p.P630S | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.003); catalogued as COSV53670422; called by muse, mutect2, varscan2
- SIX4 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 65/186 reads (35%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.227); catalogued as COSV53670433, COSV53671889; called by muse, mutect2, varscan2
- SLC13A2 | c.1580C>T p.S527F | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58992909; called by muse, mutect2, varscan2
- SLC17A1 | c.449T>C p.V150A | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.029); catalogued as rs747332834, COSV55079965; called by muse, mutect2, varscan2
- SLC17A8 | c.1513G>A p.E505K | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV60124838; called by muse, mutect2, varscan2
- SLC19A1 | c.1307C>T p.S436F | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV60590288; called by muse, mutect2, varscan2
- SLC22A10 | c.112G>C p.E38Q | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs200417874; called by muse, mutect2, varscan2
- SLC22A10 | c.830G>A p.R277K | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.731); catalogued as COSV60421987; called by muse, mutect2, varscan2
- SLC22A2 | c.1636C>T p.Q546* | Nonsense Mutation (SNP) | VAF 9/43 reads (21%) | catalogued as COSV65270485; called by muse, mutect2
- SLC22A25 | c.1071-1G>A p.X357_splice | Splice Site (SNP) | VAF 17/49 reads (35%) | catalogued as COSV60596993; called by muse, mutect2, varscan2
- SLC22A9 | c.766C>T p.R256* | Nonsense Mutation (SNP) | VAF 22/53 reads (42%) | catalogued as rs764439492, COSV54168113; called by muse, mutect2, varscan2
- SLC22A9 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.461); catalogued as rs868808864, COSV54168121; called by muse, mutect2, varscan2
- SLC25A40 | c.581C>T p.S194F | Missense Mutation (SNP) | VAF 40/142 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV62020572; called by muse, mutect2
- SLC25A52 | c.262C>T p.R88* (on ENST00000672005; = p.R78* on NM_001034172.4) | Nonsense Mutation (SNP) | VAF 34/111 reads (31%) | catalogued as COSV52502938; called by muse, mutect2, varscan2
- SLC26A8 | c.1558C>T p.R520C | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs749983760, COSV62884379; called by muse, mutect2, varscan2
- SLC37A1 | c.1600T>G p.*534Gext*32 | Nonstop Mutation (SNP) | VAF 8/43 reads (19%) | catalogued as COSV61403109; called by muse, mutect2, varscan2
- SLC38A8 | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 58/201 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.566); catalogued as rs767833817, COSV55307779; called by muse, mutect2, varscan2
- SLC6A5 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as COSV54228617; called by muse, mutect2
- SLC6A9 | c.907C>T p.L303F (on ENST00000360584 / NM_201649.4; = p.L249F on NM_006934.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 59/178 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.09); catalogued as COSV62211185; called by muse, mutect2, varscan2
- SLC6A9 | c.476C>T p.S159F (on ENST00000360584 / NM_201649.4; = p.S105F on NM_006934.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62211193; called by muse, mutect2, varscan2
- SLC9A2 | c.789G>A p.M263I | Missense Mutation (SNP) | VAF 90/146 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); catalogued as COSV52131978; called by muse, varscan2
- SLC9A8 | c.883C>T p.P295S | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100846223; called by muse, mutect2, varscan2
- SLC9A8 | c.884C>T p.P295L | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100846224; called by muse, mutect2, varscan2
- SLC9C1 | c.3191G>A p.R1064Q | Missense Mutation (SNP) | VAF 41/78 reads (53%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as rs377402243; called by muse, mutect2, varscan2
- SLIT1 | c.2161G>A p.E721K | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV99820496; called by muse, mutect2, varscan2
- SLIT2 | c.3835C>G p.L1279V | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV56578931; called by muse, mutect2, varscan2
- SLITRK1 | c.173C>T p.S58F | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (0.76); PolyPhen benign (0.068); catalogued as rs1196654231, COSV65675702; called by muse, mutect2, varscan2
- SMARCE1 | c.400C>T p.H134Y | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.111); catalogued as COSV52861273; called by muse, mutect2, varscan2
- SMG5 | c.1636T>C p.S546P | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV62436160; called by muse, mutect2, varscan2
- SMG8 | c.2744C>T p.P915L | Missense Mutation (SNP) | VAF 51/180 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759369096, COSV56284986; called by muse, mutect2, varscan2
- SNCAIP | c.511G>A p.V171M | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as rs535638935, COSV54413952; called by muse, mutect2, varscan2
- SNTG2 | c.372T>C p.V124= | Splice Region (SNP) | VAF 52/90 reads (58%) | catalogued as COSV57991616; called by muse, mutect2, varscan2
- SNX29 | c.2336G>A p.G779E | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.26); catalogued as rs746735031, COSV60063535; called by muse, mutect2
- SP140L | c.994G>A p.D332N | Missense Mutation (SNP) | VAF 69/95 reads (73%) | SIFT tolerated (0.29); PolyPhen benign (0.155); catalogued as COSV54745452; called by muse, mutect2, varscan2
- SPACA3 | c.130G>A p.G44S | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.185); catalogued as COSV52191633; called by muse, mutect2, varscan2
- SPINK5 | c.547C>T p.L183F | Missense Mutation (SNP) | VAF 44/82 reads (54%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.953); catalogued as COSV56257202; called by muse, varscan2
- SPOP | c.667C>T p.P223S | Missense Mutation (SNP) | VAF 61/185 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as COSV61653833, COSV61654517; called by muse, mutect2, varscan2
- SPTA1 | c.2728G>A p.E910K | Missense Mutation (SNP) | VAF 112/282 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267598102, COSV100934909, COSV63755764; called by muse, mutect2, varscan2
- ST6GAL2 | c.101A>G p.N34S | Missense Mutation (SNP) | VAF 33/51 reads (65%) | PolyPhen benign (0.005); catalogued as COSV64529483; called by muse, mutect2, varscan2
- STAB2 | c.1960C>T p.P654S | Missense Mutation (SNP) | VAF 50/136 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101186280, COSV66341626; called by muse, mutect2, varscan2
- STAB2 | c.2060G>A p.R687K | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66341634; called by muse, mutect2, varscan2
- STAG3 | c.548C>T p.S183F | Missense Mutation (SNP) | VAF 43/126 reads (34%) | SIFT tolerated (0.57); PolyPhen benign (0.1); catalogued as COSV57932025; called by muse, mutect2, varscan2
- STH | c.166T>G p.S56A | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.011); catalogued as rs1319419786, COSV52242364; called by muse, mutect2
- STOML3 | c.190C>T p.R64C | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs749195994, COSV65510311; called by muse, mutect2, varscan2
- STT3B | c.486A>G p.I162M | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.882); catalogued as COSV55503967; called by muse, mutect2, varscan2
- STYXL2 | c.553C>T p.Q185* | Nonsense Mutation (SNP) | VAF 24/76 reads (32%) | catalogued as COSV54806831; called by muse, mutect2
- STYXL2 | c.2221G>A p.E741K | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54806843; called by muse, mutect2, varscan2
- STYXL2 | c.3361C>T p.R1121W | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as rs759325412, COSV54802248; called by muse, mutect2, varscan2
- SULT4A1 | c.502G>A p.D168N | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.58); PolyPhen benign (0.018); catalogued as COSV50781880; called by muse, mutect2
- SVEP1 | c.8629G>A p.G2877R | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as COSV52839540; called by muse, mutect2, varscan2
- SVEP1 | c.635G>A p.R212Q | Missense Mutation (SNP) | VAF 45/79 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as rs966129907, COSV57040069; called by muse, mutect2, varscan2
677 further variants in this file (150 protein-altering or splice-affecting, 496 silent, 31 other) are not listed here.
